Somatic mutation profile of tumor specimen TCGA-D5-6928-01A (aliquot TCGA-D5-6928-01A-11D-1924-10) from TCGA case TCGA-D5-6928, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Mucinous adenocarcinoma; Tissue or organ of origin: Hepatic flexure of colon; AJCC pathologic stage: Stage IIA; Age at diagnosis: 80.5 years (29,411 days).
Specimen TCGA-D5-6928-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 67e99413-7fb3-4792-b4ab-832df54f3810.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D5-6928-10A (Blood Derived Normal), aliquot TCGA-D5-6928-10A-01D-1924-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/57769684-cdca-49ef-b0ba-dbce04dfb4ad

The open-access MAF lists 1,871 somatic variants for this specimen: 1,454 protein-altering or splice-affecting, 381 silent, 36 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 1,065, Silent 381, Frame Shift Del 243, Nonsense Mutation 60, Frame Shift Ins 43, Intron 18, Splice Site 18, Splice Region 11, In Frame Del 10, RNA 6, 3'UTR 6, 5'Flank 3.

Variants (750 of 1,871; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATM | c.6100C>T p.R2034* | Nonsense Mutation (SNP) | VAF 16/77 reads (21%) | catalogued as rs532480170, CM960102, COSV53736160; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- FBN1 | c.6953G>A p.C2318Y | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1555394626, CM098721, COSV57315962; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- FBXW7 | c.1393C>T p.R465C (on ENST00000281708 / NM_001349798.2; = p.R385C on NM_018315.5) | Missense Mutation (SNP) | VAF 12/80 reads (15%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs867384286, COSV55891008, COSV55897912, COSV99654845; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PMPCA | c.1130C>T p.A377V | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs963172852; ClinVar: likely pathogenic; called by muse, mutect2
- SLC2A1 | c.988C>T p.R330* | Nonsense Mutation (SNP) | VAF 6/15 reads (40%) | catalogued as rs80359826, CM002409, COSV65287339; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- SMARCA4 | c.2653C>T p.R885C | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs281875227, CM122492, COSV100759471, COSV60785471; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SMARCB1 | c.463C>T p.R155* (on ENST00000263121; = p.R201* on NM_003073.5) | Nonsense Mutation (SNP) | VAF 9/65 reads (14%) | catalogued as rs1555877286, CM992975, COSV54093216; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TH | c.405+1G>A p.X135_splice (on ENST00000381178 / NM_199292.3; = p.X104_splice on NM_000360.4) | Splice Site (SNP) | VAF 23/145 reads (16%) | catalogued as rs1554923802, COSV100147163; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TJP2 | c.1451del p.P484Qfs*30 | Frame Shift Del (DEL) | VAF 5/34 reads (15%) | catalogued as rs1554662952; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- TTN | c.12107del p.P4036Qfs*14 (on ENST00000591111; = p.P3990Qfs*14 on NM_003319.4) | Frame Shift Del (DEL) | VAF 17/93 reads (18%) | catalogued as rs1408345511; ClinVar: likely pathogenic; called by mutect2, varscan2
- AACS | c.1075del p.L359Wfs*15 | Frame Shift Del (DEL) | VAF 18/54 reads (33%) | catalogued as COSV55538357; called by mutect2, pindel, varscan2
- ABCA10 | c.3110T>G p.I1037S | Missense Mutation (SNP) | VAF 42/190 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV52221766; called by muse, varscan2
- ABCA12 | c.1894C>T p.Q632* (on ENST00000272895 / NM_173076.3; = p.Q314* on NM_015657.3) | Nonsense Mutation (SNP) | VAF 8/82 reads (10%) | catalogued as COSV55958403; called by muse, mutect2
- ABCB11 | c.1822C>T p.H608Y | Missense Mutation (SNP) | VAF 18/79 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.209); catalogued as COSV55590138; called by muse, mutect2, varscan2
- ABCB4 | c.3137G>A p.R1046Q | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs774151533, COSV55934974; called by muse, mutect2, varscan2
- ABHD15 | c.1046C>T p.A349V | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV56195158; called by muse, mutect2, varscan2
- ABR | c.1969C>T p.R657C (on ENST00000302538 / NM_021962.5; = p.R620C on NM_001092.5) | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated (0.05); PolyPhen benign (0.109); catalogued as rs779303661, COSV99348506; called by muse, mutect2
- ACACB | c.5971G>A p.V1991I | Missense Mutation (SNP) | VAF 15/102 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0.026); catalogued as COSV58134048; called by muse, mutect2, varscan2
- ACADS | c.233G>A p.G78E | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as COSV54368848; called by muse, mutect2, varscan2
- ACBD7 | c.257A>G p.Y86C | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV62252477; called by muse, mutect2, varscan2
- ACKR1 | c.505C>T p.L169F | Missense Mutation (SNP) | VAF 7/68 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.933); catalogued as COSV63672718; called by muse, mutect2
- ACO2 | c.1672G>A p.V558M | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.277); catalogued as rs1052489466, COSV53442722; called by muse, mutect2, varscan2
- ACP1 | c.447C>A p.C149* | Nonsense Mutation (SNP) | VAF 23/116 reads (20%) | catalogued as COSV55243128; called by muse, mutect2, varscan2
- ACSM3 | c.103G>A p.A35T | Missense Mutation (SNP) | VAF 23/114 reads (20%) | SIFT tolerated (0.21); PolyPhen benign (0.021); catalogued as COSV56844245; called by muse, mutect2, varscan2
- ACTA1 | c.911G>A p.G304D | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as CD142756, COSV64203291; called by muse, mutect2, varscan2
- ACTN4 | c.283C>T p.R95W | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs771850037, COSV53145815; called by muse, mutect2, varscan2
- ACVR1B | c.646G>A p.G216S | Missense Mutation (SNP) | VAF 20/141 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57777072; called by muse, mutect2, varscan2
- ACVR2A | c.1310del p.K437Rfs*5 | Frame Shift Del (DEL) | VAF 20/51 reads (39%) | catalogued as rs764719749, COSV104385546; called by mutect2, varscan2
- ADAM15 | c.2333C>A p.P778H | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.998); catalogued as COSV55126733; called by muse, mutect2, varscan2
- ADAM21 | c.1204G>A p.E402K | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs375714568, COSV50791466; called by mutect2, varscan2
- ADAM28 | c.1423C>T p.P475S | Missense Mutation (SNP) | VAF 25/146 reads (17%) | SIFT deleterious (0.05); PolyPhen benign (0.021); catalogued as COSV56100297; called by muse, mutect2, varscan2
- ADAM30 | c.923C>T p.S308L | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.871); catalogued as rs777903328, COSV65561036; called by muse, mutect2, varscan2
- ADAM32 | c.1292A>G p.K431R | Missense Mutation (SNP) | VAF 19/98 reads (19%) | SIFT tolerated (0.39); PolyPhen benign (0.015); catalogued as COSV65949041; called by muse, mutect2, varscan2
- ADAMTS10 | c.196C>T p.R66C | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.885); catalogued as rs782504616, COSV54353199, COSV99547557; called by muse, mutect2, varscan2
- ADAMTS13 | c.540-1G>T p.X180_splice | Splice Site (SNP) | VAF 9/25 reads (36%) | catalogued as COSV63021172; called by muse, mutect2, varscan2
- ADAMTS20 | c.4112C>T p.S1371L | Missense Mutation (SNP) | VAF 16/77 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.138); catalogued as COSV67131096; called by muse, mutect2, varscan2
- ADCK1 | c.701A>G p.E234G | Missense Mutation (SNP) | VAF 15/109 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV53080549; called by muse, mutect2, varscan2
- ADCY3 | c.2522C>A p.S841Y | Missense Mutation (SNP) | VAF 15/149 reads (10%) | SIFT tolerated (0.28); PolyPhen benign (0.109); catalogued as COSV53167357; called by muse, mutect2, varscan2
- ADCY6 | c.1052C>T p.A351V | Missense Mutation (SNP) | VAF 16/173 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV57167753; called by muse, mutect2, varscan2
- ADCY6 | c.767G>A p.R256H | Missense Mutation (SNP) | VAF 17/122 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.429); catalogued as rs1281566095, COSV57167759; called by muse, mutect2, varscan2
- ADGRA2 | c.1573del p.A525Pfs*12 | Frame Shift Del (DEL) | VAF 5/51 reads (10%) | catalogued as rs760256806, COSV59443632; called by mutect2, pindel
- ADGRF1 | c.1276C>T p.R426W | Missense Mutation (SNP) | VAF 27/165 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.446); catalogued as rs773948526, COSV51945392; called by muse, mutect2, varscan2
- ADGRF3 | c.2839G>T p.A947S (on ENST00000311519 / NM_001145168.1; = p.A748S on NM_153835.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.643); catalogued as COSV61050173; called by muse, mutect2, varscan2
- ADGRL2 | c.1728G>T p.Q576H | Missense Mutation (SNP) | VAF 10/93 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV54665860; called by muse, mutect2, varscan2
- ADGRL3 | c.335G>A p.R112H (on ENST00000506720 / NM_001322402.2; = p.R44H on NM_015236.6) | Missense Mutation (SNP) | VAF 12/86 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1284975701, COSV72268248; called by muse, mutect2, varscan2
- ADGRV1 | c.679G>T p.E227* | Nonsense Mutation (SNP) | VAF 9/94 reads (10%) | catalogued as COSV67984730; called by muse, mutect2, varscan2
- ADH1B | c.599G>A p.G200D | Missense Mutation (SNP) | VAF 32/156 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV100520857; called by muse, mutect2, varscan2
- ADRA1B | c.755C>T p.T252I | Missense Mutation (SNP) | VAF 22/134 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.259); catalogued as COSV100140417; called by muse, mutect2, varscan2
- ADRA2B | c.370C>T p.R124C | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV69787495, COSV69787618; called by muse, mutect2, varscan2
- AFAP1L1 | c.1513G>A p.G505R | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs761420859, COSV57045095, COSV99695867; called by muse, mutect2, varscan2
- AFF2 | c.1813C>T p.P605S | Missense Mutation (SNP) | VAF 34/81 reads (42%) | SIFT tolerated (0.17); PolyPhen benign (0.108); catalogued as COSV53976013, COSV53988355; called by muse, mutect2, varscan2
- AHCY | c.106C>T p.R36W | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.583); catalogued as COSV54153193; called by muse, mutect2, varscan2
- AHNAK | c.15584C>T p.S5195F | Missense Mutation (SNP) | VAF 19/129 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV57212686; called by muse, mutect2, varscan2
- AHNAK | c.6446C>A p.P2149H | Missense Mutation (SNP) | VAF 14/99 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57212700; called by muse, mutect2, varscan2
- AHNAK2 | c.13252A>G p.T4418A | Missense Mutation (SNP) | VAF 17/77 reads (22%) | SIFT tolerated (0.7); PolyPhen possibly damaging (0.757); catalogued as COSV60914805; called by muse, mutect2, varscan2
- AHSG | c.853G>A p.A285T | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT tolerated (0.58); PolyPhen benign (0.005); catalogued as rs766181399, COSV56607693; called by mutect2, varscan2
- AIDA | c.750_752del p.R251del | In Frame Del (DEL) | VAF 24/172 reads (14%) | catalogued as COSV60512563; called by mutect2, pindel, varscan2
- ALAS2 | c.844G>A p.A282T | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.975); catalogued as rs368251919, COSV58190263; called by muse, mutect2, varscan2
- ALDH16A1 | c.766C>T p.R256C | Missense Mutation (SNP) | VAF 30/79 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as rs756830979, COSV53194076; called by muse, mutect2
- ALDH1A2 | c.52G>A p.A18T | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.174); catalogued as rs1283761840, COSV51078204; called by muse, mutect2, varscan2
- ALDH2 | c.631G>A p.A211T | Missense Mutation (SNP) | VAF 16/129 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV55667032; called by muse, mutect2, varscan2
- ALDH3A1 | c.1334del p.P445Rfs*6 | Frame Shift Del (DEL) | VAF 5/41 reads (12%) | catalogued as rs778623472, COSV56735668; called by mutect2, pindel, varscan2
- ALDOB | c.167G>A p.R56H | Missense Mutation (SNP) | VAF 26/196 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs200050226, COSV66397806; called by muse, mutect2, varscan2
- ALPK1 | c.9T>A p.N3K | Missense Mutation (SNP) | VAF 9/117 reads (8%) | SIFT tolerated (0.05); PolyPhen benign (0.073); catalogued as COSV99455079; called by muse, mutect2
- AMDHD2 | c.414C>T p.L138= | Splice Region (SNP) | VAF 7/34 reads (21%) | catalogued as rs757372674, COSV53550649; called by muse, mutect2, varscan2
- AMPD2 | c.223-3del | Splice Region (DEL) | VAF 7/38 reads (18%) | catalogued as rs770280481; called by mutect2, pindel, varscan2
- ANGPT2 | c.693A>T p.E231D | Missense Mutation (SNP) | VAF 22/189 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.341); catalogued as COSV57336807; called by muse, mutect2, varscan2
- ANK2 | c.3970G>A p.V1324I | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1261943601, COSV52154963; called by muse, mutect2, varscan2
- ANK2 | c.7550C>T p.A2517V | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.997); catalogued as rs756461250, COSV52159994; called by mutect2, varscan2
- ANK3 | c.12420del p.K4140Nfs*15 (on ENST00000280772 / NM_001320874.2; = p.K661Nfs*15 on NM_001149.3) | Frame Shift Del (DEL) | VAF 8/50 reads (16%) | catalogued as rs1466658148; called by mutect2, varscan2
- ANKRD44 | c.2651A>G p.Q884R | Missense Mutation (SNP) | VAF 30/160 reads (19%) | SIFT tolerated (0.22); PolyPhen benign (0.019); catalogued as COSV99985899; called by muse, mutect2, varscan2
- ANTXR2 | c.958G>A p.A320T | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.677); catalogued as rs756324499, COSV56313262; called by mutect2, varscan2
- AP002748.5 | c.64G>A p.A22T | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.003); catalogued as rs908552853, COSV59148513; called by muse, mutect2, varscan2
- AP3B2 | c.1627A>G p.N543D | Missense Mutation (SNP) | VAF 8/73 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99916946; called by mutect2, varscan2
- AQP10 | c.185G>A p.G62D | Missense Mutation (SNP) | VAF 18/149 reads (12%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.543); catalogued as COSV61474946; called by muse, varscan2
- ARFGEF1 | c.4655del p.P1552Hfs*6 | Frame Shift Del (DEL) | VAF 8/73 reads (11%) | catalogued as COSV51619799; called by mutect2, pindel
- ARHGAP17 | c.1744C>A p.P582T (on ENST00000289968 / NM_001006634.3; = p.P504T on NM_018054.6) | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0.01); catalogued as rs1345632972, COSV51506911; called by muse, mutect2, varscan2
- ARHGAP44 | c.2449G>A p.A817T | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.007); catalogued as rs1161462360, COSV52391221; called by muse, mutect2, varscan2
- ARHGAP45 | c.994-1G>A p.X332_splice | Splice Site (SNP) | VAF 17/88 reads (19%) | catalogued as COSV57431704; called by muse, mutect2, varscan2
- ARHGAP6 | c.683A>G p.Q228R | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.376); catalogued as COSV57295623; called by muse, mutect2, varscan2
- ARHGEF17 | c.5053G>T p.E1685* | Nonsense Mutation (SNP) | VAF 9/40 reads (23%) | catalogued as COSV55232345; called by muse, mutect2, varscan2
- ARID2 | c.1418C>A p.S473Y | Missense Mutation (SNP) | VAF 15/97 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.467); catalogued as COSV57603072; called by muse, mutect2, varscan2
- ARL6 | c.230G>T p.R77I | Missense Mutation (SNP) | VAF 12/160 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60117500; called by muse, mutect2
- ARNT2 | c.293G>A p.R98Q | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs1326668677, COSV57585005; called by muse, mutect2, varscan2
- ARSI | c.940C>T p.R314C | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.055); catalogued as rs776520005, COSV60817216; called by muse, mutect2, varscan2
- ASAH2 | c.1114G>A p.A372T | Missense Mutation (SNP) | VAF 39/238 reads (16%) | SIFT tolerated (0.4); PolyPhen benign (0.151); catalogued as rs1265280264, COSV61483535; called by muse, mutect2, varscan2
- ASB15 | c.962C>T p.A321V | Missense Mutation (SNP) | VAF 26/139 reads (19%) | SIFT tolerated (0.96); PolyPhen benign (0.007); catalogued as COSV51929799; called by muse, mutect2, varscan2
- ASCL4 | c.39G>T p.L13F | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.807); catalogued as rs565285072, COSV60816572; called by muse, mutect2, varscan2
- ASL | c.956G>A p.S319N | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.105); catalogued as rs774195710, COSV59188398; called by muse, mutect2, varscan2
- ASL | c.1325G>A p.G442D | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59188403; called by mutect2, varscan2
- ASMTL | c.986A>G p.D329G | Missense Mutation (SNP) | VAF 36/177 reads (20%) | SIFT tolerated (0.76); PolyPhen benign (0.006); catalogued as COSV67243605; called by muse, mutect2, varscan2
- ASPHD1 | c.368C>T p.S123L | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as rs925939730, COSV58099258; called by muse, mutect2, varscan2
- ASPM | c.8379G>A p.M2793I | Missense Mutation (SNP) | VAF 10/89 reads (11%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs376057172; called by mutect2, varscan2
- ATG4D | c.946G>A p.V316M | Missense Mutation (SNP) | VAF 16/92 reads (17%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.953); catalogued as rs748483612, COSV57264161; called by muse, mutect2, varscan2
- ATL1 | c.1054G>A p.A352T | Missense Mutation (SNP) | VAF 24/150 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.667); catalogued as COSV63296383; called by muse, mutect2, varscan2
- ATN1 | c.1198C>T p.P400S | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.013); catalogued as COSV63110981; called by muse, mutect2, varscan2
- ATP10A | c.1652C>T p.A551V | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT tolerated (0.51); PolyPhen benign (0.013); catalogued as rs751938420, COSV63517024; called by muse, mutect2, varscan2
- ATP13A2 | c.2746G>A p.V916M | Missense Mutation (SNP) | VAF 16/104 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.696); catalogued as rs768674400, COSV58700362; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ATP2B1 | c.3301C>T p.R1101W | Missense Mutation (SNP) | VAF 12/105 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.711); catalogued as rs746094247, COSV53807246; called by muse, mutect2, varscan2
- ATP2C2 | c.418G>A p.A140T | Missense Mutation (SNP) | VAF 22/130 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.341); catalogued as COSV52295790; called by muse, mutect2, varscan2
- ATP6V0D1 | c.713C>T p.A238V | Missense Mutation (SNP) | VAF 20/95 reads (21%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.668); catalogued as COSV99341317; called by muse, varscan2
- ATP6V1E2 | c.595C>T p.R199* | Nonsense Mutation (SNP) | VAF 23/127 reads (18%) | catalogued as rs200757763; called by muse, mutect2, varscan2
- ATP8B3 | c.3734C>A p.S1245Y | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.556); catalogued as COSV100034917; called by muse, mutect2, varscan2
- ATRNL1 | c.1348+1G>A p.X450_splice | Splice Site (SNP) | VAF 19/100 reads (19%) | catalogued as COSV61803637; called by muse, mutect2, varscan2
- ATRNL1 | c.2993G>A p.C998Y | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58087036; called by muse, mutect2, varscan2
- ATXN1 | c.1030C>A p.L344M | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.942); catalogued as COSV55215611; called by mutect2, varscan2
- AURKB | c.894G>T p.M298I | Missense Mutation (SNP) | VAF 19/81 reads (23%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs768656332, COSV60244466; called by muse, mutect2, varscan2
- B3GNT3 | c.787C>T p.R263W | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.892); catalogued as rs763164172, COSV57953173; called by mutect2, varscan2
- B4GALNT4 | c.2972del p.G991Vfs*71 | Frame Shift Del (DEL) | VAF 10/47 reads (21%) | catalogued as rs35951843; called by mutect2, pindel, varscan2
- B4GALT5 | c.646G>A p.V216I | Missense Mutation (SNP) | VAF 5/54 reads (9%) | SIFT tolerated (0.29); PolyPhen benign (0.195); catalogued as rs200086193, COSV65493589; called by mutect2, varscan2
- B4GALT7 | c.467C>T p.T156M | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.915); catalogued as rs145129446; called by muse, mutect2, varscan2
- B4GAT1 | c.796C>T p.R266C | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.836); catalogued as rs1455459346, COSV60820037; called by muse, mutect2
- BACH1 | c.809G>A p.C270Y | Missense Mutation (SNP) | VAF 12/94 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.289); catalogued as rs746048388, COSV54518777; called by muse, mutect2, varscan2
- BAP1 | c.619C>T p.R207W | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.725); catalogued as rs1323972421, COSV56234105; called by muse, mutect2, varscan2
- BASP1 | c.215A>T p.E72V | Missense Mutation (SNP) | VAF 17/73 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.026); catalogued as COSV59470892; called by muse, mutect2
- BBS7 | c.319C>A p.L107I | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.935); catalogued as COSV52656421; called by muse, mutect2, varscan2
- BBX | c.1834G>T p.E612* | Nonsense Mutation (SNP) | VAF 25/120 reads (21%) | catalogued as COSV57880212, COSV57881518, COSV57884048; called by muse, mutect2, varscan2
- BCAR3 | c.863G>T p.R288M | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.2); catalogued as COSV53074821; called by muse, mutect2, varscan2
- BCL7C | c.358del p.Q120Sfs*33 | Frame Shift Del (DEL) | VAF 9/39 reads (23%) | catalogued as rs758526156; called by mutect2, pindel, varscan2
- BCLAF1 | c.685C>T p.P229S | Missense Mutation (SNP) | VAF 12/134 reads (9%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.986); catalogued as rs1442583009, COSV62142012; called by muse, mutect2
- BCOR | c.1708G>A p.A570T | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.995); catalogued as rs748813798, COSV60706581; ClinVar: likely benign; called by muse, mutect2, varscan2
- BCS1L | c.758T>C p.L253P | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.081); catalogued as COSV55307241; called by muse, mutect2, varscan2
- BDP1 | c.5091G>T p.E1697D | Missense Mutation (SNP) | VAF 34/222 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.23); catalogued as COSV100703468; called by muse, mutect2, varscan2
- BIN3 | c.568C>T p.R190C | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs750251598, COSV52384460; called by muse, mutect2, varscan2
- BMP2 | c.979G>A p.G327R | Missense Mutation (SNP) | VAF 11/103 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs190569855, COSV66577805; called by muse, mutect2, varscan2
- BMP8A | c.1198G>A p.G400S | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs770474598, COSV59032748; called by mutect2, varscan2
- BPTF | c.7946G>A p.R2649H | Missense Mutation (SNP) | VAF 23/164 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.974); catalogued as rs782594079, COSV58832726; called by muse, mutect2, varscan2
- BRD4 | c.1267C>T p.R423* | Nonsense Mutation (SNP) | VAF 7/70 reads (10%) | catalogued as COSV54586032; called by muse, mutect2, varscan2
- BRSK1 | c.347del p.G116Vfs*8 | Frame Shift Del (DEL) | VAF 14/113 reads (12%) | catalogued as rs776865070; called by mutect2, pindel, varscan2
- BRSK2 | c.37G>A p.A13T | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated (0.23); PolyPhen benign (0.009); catalogued as COSV57542987; called by muse, mutect2, varscan2
- C17orf97 | c.560G>A p.R187H | Missense Mutation (SNP) | VAF 22/123 reads (18%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.982); catalogued as rs141704289; called by muse, mutect2, varscan2
- C1QA | c.185G>T p.G62V | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); catalogued as rs960202389, COSV65889537; called by muse, mutect2, varscan2
- C1R | c.955G>A p.E319K (on ENST00000536053 / NM_001354346.2; = p.E305K on NM_001733.7) | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.181); catalogued as rs767341899, COSV73293822; called by muse, mutect2, varscan2
- C1orf189 | c.262G>A p.E88K | Missense Mutation (SNP) | VAF 50/253 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV63890947; called by muse, mutect2, varscan2
- CA5A | c.692C>T p.A231V | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.184); catalogued as rs373280084; called by muse, mutect2, varscan2
- CACNA1D | c.5311C>T p.R1771W (on ENST00000350061 / NM_001128840.3; = p.R1791W on NM_000720.4) | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.003); catalogued as rs535459203, COSV99859798; called by mutect2, varscan2
- CACNA1F | c.365C>A p.T122N | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated (0.33); PolyPhen benign (0.036); catalogued as COSV59904356; called by muse, mutect2, varscan2
- CACNA2D4 | c.1712G>T p.R571L | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs781270397, COSV54949832; called by muse, mutect2, varscan2
- CACNB2 | c.1433G>A p.R478H (on ENST00000324631 / NM_201596.3; = p.R423H on NM_000724.4) | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.814); catalogued as rs781646326, COSV56622648; ClinVar: uncertain significance; called by mutect2, varscan2
- CADM2 | c.155C>A p.T52N (on ENST00000407528 / NM_001167674.2; = p.T54N on NM_153184.4) | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67372857; called by muse, mutect2, varscan2
- CALCRL | c.48del p.F16Lfs*2 | Frame Shift Del (DEL) | VAF 9/68 reads (13%) | catalogued as rs1486659949; called by mutect2, pindel, varscan2
- CAMKK2 | c.199G>A p.G67S | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); catalogued as rs746435585, COSV61214618; called by mutect2, varscan2
- CAMKV | c.638T>G p.L213R | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV56555288; called by muse, mutect2
- CAMP | c.491dup p.L164Ffs*26 (on ENST00000296435; = p.L161Ffs*26 on NM_004345.5) | Frame Shift Ins (INS) | VAF 5/35 reads (14%) | catalogued as rs753541088; called by mutect2, pindel, varscan2
- CAMTA2 | c.2597del p.P866Lfs*9 | Frame Shift Del (DEL) | VAF 7/19 reads (37%) | catalogued as rs745547658; called by mutect2, varscan2
- CAPN10 | c.1592dup p.S532Qfs*38 | Frame Shift Ins (INS) | VAF 8/48 reads (17%) | catalogued as rs779173614; called by mutect2, pindel, varscan2
- CARD10 | c.3095C>A p.A1032D | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.503); catalogued as COSV99325335; called by muse, mutect2
- CARD11 | c.509G>A p.R170H | Missense Mutation (SNP) | VAF 29/125 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.172); catalogued as rs766268425, COSV62716853, COSV62719430, COSV62719971; called by muse, mutect2, varscan2
- CARD6 | c.1375C>T p.R459C | Missense Mutation (SNP) | VAF 7/73 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs561968147, COSV54566047; called by mutect2, varscan2
- CASP8 | c.1068del p.F356Lfs*26 (on ENST00000432109 / NM_033355.3; = p.F373Lfs*26 on NM_001228.4) | Frame Shift Del (DEL) | VAF 9/46 reads (20%) | catalogued as COSV51847031; called by mutect2, pindel, varscan2
- CASR | c.1834G>A p.V612M (on ENST00000490131; = p.V689M on NM_000388.4) | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as CM040393, COSV56137227; called by muse, mutect2, varscan2
- CATSPERE | c.1415A>T p.N472I | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100835346; called by muse, mutect2
- CAVIN4 | c.104C>T p.T35I | Missense Mutation (SNP) | VAF 34/132 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as rs1360905485, COSV56867104; called by muse, mutect2, varscan2
- CBLB | c.2888C>T p.A963V | Missense Mutation (SNP) | VAF 22/129 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs1325540559, COSV51426258; called by muse, mutect2, varscan2
- CCDC110 | c.518G>T p.R173I | Missense Mutation (SNP) | VAF 36/213 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.216); catalogued as COSV56872261; called by muse, mutect2, varscan2
- CCDC124 | c.124G>A p.D42N | Missense Mutation (SNP) | VAF 13/79 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.006); catalogued as rs778475492, COSV71490379; called by muse, mutect2, varscan2
- CCDC184 | c.250C>T p.R84* | Nonsense Mutation (SNP) | VAF 8/65 reads (12%) | catalogued as COSV57251903; called by muse, mutect2, varscan2
- CCDC198 | c.517A>G p.S173G | Missense Mutation (SNP) | VAF 33/157 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.124); catalogued as COSV53602000; called by muse, mutect2, varscan2
- CCDC30 | c.442del p.T148Lfs*6 (on ENST00000340612; = p.T105Lfs*6 on NM_001080850.3) | Frame Shift Del (DEL) | VAF 24/160 reads (15%) | catalogued as rs775731046; called by mutect2, pindel, varscan2
- CCDC61 | c.107G>A p.R36Q | Missense Mutation (SNP) | VAF 98/257 reads (38%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.802); catalogued as rs373145203, COSV54428309; called by muse, mutect2, varscan2
- CCDC73 | c.2683del p.T895Lfs*8 | Frame Shift Del (DEL) | VAF 10/88 reads (11%) | catalogued as rs764792181; called by mutect2, pindel, varscan2
- CCDC9B | c.294del p.M99Wfs*3 | Frame Shift Del (DEL) | VAF 6/42 reads (14%) | catalogued as rs765438623; called by mutect2, pindel
- CCNA1 | c.108G>A p.Q36= | Splice Region (SNP) | VAF 14/81 reads (17%) | catalogued as COSV55219692, COSV55221357; called by muse, mutect2, varscan2
- CCNB1 | c.815T>G p.V272G | Missense Mutation (SNP) | VAF 23/142 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV56509959; called by muse, mutect2, varscan2
- CCNB2 | c.496C>T p.R166C | Missense Mutation (SNP) | VAF 22/127 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs759811496, COSV55595051; called by muse, mutect2, varscan2
- CCNG2 | c.938G>A p.C313Y | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.172); catalogued as COSV60353621; called by muse, mutect2, varscan2
- CCT5 | c.1360G>A p.A454T | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.267); catalogued as rs1014806791, COSV54723982, COSV99725563; called by muse, mutect2, varscan2
- CD109 | c.1917G>T p.W639C | Missense Mutation (SNP) | VAF 16/80 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as COSV54649149; called by muse, mutect2, varscan2
- CD320 | c.149G>A p.S50N | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.175); catalogued as COSV56848363; called by muse, mutect2, varscan2
- CD40LG | c.524T>C p.V175A | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV65698449; called by muse, mutect2, varscan2
- CD80 | c.161T>C p.V54A | Missense Mutation (SNP) | VAF 22/137 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.41); catalogued as COSV51802211; called by muse, mutect2, varscan2
- CD93 | c.952G>A p.V318I | Missense Mutation (SNP) | VAF 21/78 reads (27%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs140540216, COSV55664977; called by muse, mutect2, varscan2
- CDC14A | c.375del p.Y126Ifs*64 | Frame Shift Del (DEL) | VAF 19/116 reads (16%) | catalogued as rs773911500; called by mutect2, pindel, varscan2
- CDC42BPB | c.4153A>G p.R1385G | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.788); catalogued as COSV100775586, COSV63474915; called by muse, mutect2, varscan2
- CDH1 | c.263C>A p.P88H | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT tolerated (0.16); PolyPhen benign (0.031); catalogued as COSV55732311, COSV55740401; called by muse, mutect2, varscan2
- CDH19 | c.1331A>G p.E444G | Missense Mutation (SNP) | VAF 12/91 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV50958376; called by muse, mutect2, varscan2
- CDH20 | c.2042C>T p.A681V | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT tolerated (0.15); PolyPhen benign (0.079); catalogued as COSV53004433; called by muse, mutect2, varscan2
- CDH4 | c.610C>T p.R204W | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.994); catalogued as rs751431226, COSV64652166; called by muse, mutect2, varscan2
- CDHR2 | c.3668T>C p.L1223P | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV99992132; called by mutect2, varscan2
- CDK18 | c.851C>T p.A284V (on ENST00000506784 / NM_212503.3; = p.A254V on NM_002596.4) | Missense Mutation (SNP) | VAF 28/181 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.431); catalogued as COSV63727407; called by muse, mutect2, varscan2
- CDK5R1 | c.109A>C p.K37Q | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT tolerated (0.42); PolyPhen probably damaging (0.987); catalogued as COSV55578703; called by muse, mutect2, varscan2
- CDKN1B | c.511G>T p.E171* | Nonsense Mutation (SNP) | VAF 5/38 reads (13%) | catalogued as COSV57430316; called by muse, mutect2, varscan2
- CDYL | c.62A>G p.Y21C | Missense Mutation (SNP) | VAF 16/127 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.041); catalogued as COSV100190043; called by muse, mutect2
- CEACAM16 | c.1054C>T p.R352C | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs747961516, COSV101312749; called by muse, mutect2
- CEACAM20 | c.1175C>A p.S392Y | Missense Mutation (SNP) | VAF 57/135 reads (42%) | SIFT tolerated (0.74); PolyPhen possibly damaging (0.772); catalogued as rs1568451400, COSV57601674; called by muse, mutect2, varscan2
- CEACAM8 | c.856A>G p.I286V | Missense Mutation (SNP) | VAF 67/564 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.852); catalogued as COSV54990706; called by muse, mutect2, varscan2
- CELSR2 | c.5486C>T p.T1829I | Missense Mutation (SNP) | VAF 13/74 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.034); catalogued as COSV54771327; called by muse, mutect2, varscan2
- CEP128 | c.904C>T p.R302* | Nonsense Mutation (SNP) | VAF 4/37 reads (11%) | catalogued as rs1476633409, COSV99383632; called by muse, mutect2
- CEP131 | c.2125C>T p.R709* (on ENST00000269392 / NM_001319228.2; = p.R706* on NM_014984.4) | Nonsense Mutation (SNP) | VAF 21/153 reads (14%) | catalogued as rs1386860991, COSV99488955; called by muse, mutect2, varscan2
- CEP19 | c.89G>T p.R30L | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56359643; called by mutect2, varscan2
- CEP192 | c.6256G>A p.D2086N | Missense Mutation (SNP) | VAF 20/87 reads (23%) | SIFT tolerated (0.22); PolyPhen benign (0.104); catalogued as rs780273702, COSV58063662; called by muse, mutect2, varscan2
- CEP290 | c.635del p.N212Tfs*14 | Frame Shift Del (DEL) | VAF 10/88 reads (11%) | catalogued as rs769091629, COSV99063658; called by mutect2, varscan2
- CEP41 | c.391G>A p.A131T | Missense Mutation (SNP) | VAF 7/89 reads (8%) | SIFT tolerated (0.19); PolyPhen benign (0.006); catalogued as rs1554417794, COSV99782887; called by muse, mutect2
- CFAP65 | c.1775del p.P592Lfs*8 | Frame Shift Del (DEL) | VAF 20/138 reads (14%) | catalogued as rs778664468; called by mutect2, pindel, varscan2
- CHAD | c.931C>A p.L311I | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); catalogued as COSV51972341; called by muse, mutect2, varscan2
- CHD1L | c.938A>G p.N313S | Missense Mutation (SNP) | VAF 12/92 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.453); catalogued as COSV63613846; called by muse, mutect2, varscan2
- CHD4 | c.218del p.K73Rfs*129 | Frame Shift Del (DEL) | VAF 52/430 reads (12%) | catalogued as rs1322050057; called by mutect2, pindel, varscan2
- CHD6 | c.2229G>T p.K743N | Missense Mutation (SNP) | VAF 17/130 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58556862; called by muse, mutect2, varscan2
- CHMP5 | c.376G>A p.D126N | Missense Mutation (SNP) | VAF 19/76 reads (25%) | SIFT tolerated (0.13); PolyPhen benign (0.08); catalogued as rs758726437, COSV56302946; called by muse, mutect2, varscan2
- CHPF2 | c.1151_1153del p.F384del | In Frame Del (DEL) | VAF 7/47 reads (15%) | catalogued as rs975336786; called by mutect2, pindel, varscan2
- CHRAC1 | c.80T>C p.I27T | Missense Mutation (SNP) | VAF 5/52 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.979); catalogued as COSV99636275; called by muse, mutect2, varscan2
- CHRD | c.449G>A p.R150H | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.482); catalogued as COSV52607731; called by muse, mutect2
- CHRDL2 | c.337C>T p.H113Y | Missense Mutation (SNP) | VAF 28/208 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as COSV55222710; called by muse, mutect2, varscan2
- CHRNA4 | c.493G>A p.V165I | Missense Mutation (SNP) | VAF 10/96 reads (10%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.698); catalogued as rs762764855, COSV64719396; ClinVar: uncertain significance; called by mutect2, varscan2
- CHST12 | c.430C>T p.R144C | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs1280290819, COSV51674956; called by muse, mutect2, varscan2
- CHTF18 | c.2828G>A p.R943H | Missense Mutation (SNP) | VAF 17/94 reads (18%) | SIFT tolerated (0.25); PolyPhen benign (0.012); catalogued as rs373749220, COSV50210967; called by muse, mutect2, varscan2
- CIBAR2 | c.66G>T p.E22D | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.766); catalogued as COSV73320599; called by muse, mutect2, varscan2
- CIC | c.901T>C p.S301P | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV50566981; called by muse, mutect2, varscan2
- CIP2A | c.2332G>A p.A778T | Missense Mutation (SNP) | VAF 12/99 reads (12%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs1480396866, COSV55418606; called by muse, mutect2
- CKAP2 | c.1817del p.K606Rfs*14 (on ENST00000378037 / NM_001098525.2; = p.K605Rfs*14 on NM_018204.5) | Frame Shift Del (DEL) | VAF 10/50 reads (20%) | catalogued as rs752250702; called by mutect2, varscan2
- CLCA1 | c.953C>T p.A318V | Missense Mutation (SNP) | VAF 13/101 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.23); catalogued as rs371482526; called by muse, mutect2, varscan2
- CLCA4 | c.2363G>A p.R788H | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT tolerated (0.49); PolyPhen benign (0.001); catalogued as rs374250322; called by mutect2, varscan2
- CLCN2 | c.1142del p.P381Lfs*35 | Frame Shift Del (DEL) | VAF 9/59 reads (15%) | catalogued as rs1217596296; called by mutect2, pindel, varscan2
- CLEC11A | c.132G>T p.E44D | Missense Mutation (SNP) | VAF 19/154 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.935); catalogued as COSV51573927; called by muse, mutect2, varscan2
- CLEC14A | c.808G>A p.A270T | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT tolerated (0.35); PolyPhen benign (0.01); catalogued as COSV60562450; called by muse, mutect2, varscan2
- CLEC4A | c.284del p.N95Ifs*49 | Frame Shift Del (DEL) | VAF 8/48 reads (17%) | catalogued as rs760557093; called by mutect2, varscan2
- CLINT1 | c.305G>A p.R102K | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51623829; called by muse, mutect2, varscan2
- CLPTM1 | c.1780C>T p.R594* | Nonsense Mutation (SNP) | VAF 19/53 reads (36%) | catalogued as COSV61611812; called by muse, mutect2, varscan2
- CLSTN1 | c.2333G>A p.R778Q (on ENST00000377298 / NM_001009566.3; = p.R768Q on NM_014944.4) | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.382); catalogued as rs781337343, COSV63648047; called by muse, mutect2, varscan2
- CLTCL1 | c.3734G>A p.R1245H | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.036); catalogued as rs782735553, COSV54230140; called by muse, mutect2, varscan2
- CLYBL | c.626C>T p.A209V | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.951); catalogued as rs1194219997, COSV100185670; called by muse, mutect2
- CNIH1 | c.400C>A p.L134I | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV53594456; called by muse, mutect2, varscan2
- CNKSR2 | c.806C>T p.T269I | Missense Mutation (SNP) | VAF 9/85 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV54255618; called by muse, mutect2, varscan2
- CNOT1 | c.613G>A p.A205T | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as rs369585591; called by mutect2, varscan2
- CNTLN | c.2741C>T p.T914I | Missense Mutation (SNP) | VAF 20/188 reads (11%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV99265469; called by muse, varscan2
- CNTN3 | c.2362C>T p.P788S | Missense Mutation (SNP) | VAF 16/129 reads (12%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.777); catalogued as COSV55170592; called by muse, mutect2, varscan2
- CNTN6 | c.484A>G p.N162D | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.005); catalogued as COSV63171336; called by muse, mutect2, varscan2
- CNTN6 | c.1253del p.K418Sfs*63 | Frame Shift Del (DEL) | VAF 28/218 reads (13%) | catalogued as rs758676375; called by mutect2, varscan2
- CNTNAP3 | c.1867A>G p.N623D | Missense Mutation (SNP) | VAF 36/295 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.029); catalogued as COSV99905542; called by muse, varscan2
- CNTROB | c.376G>A p.A126T | Missense Mutation (SNP) | VAF 10/77 reads (13%) | SIFT tolerated (0.57); PolyPhen benign (0.001); catalogued as rs763290328, COSV58051202; called by muse, mutect2, varscan2
- COL11A1 | c.3277-1G>T p.X1093_splice | Splice Site (SNP) | VAF 10/119 reads (8%) | catalogued as COSV62175632; called by muse, mutect2
- COL25A1 | c.1297G>T p.G433C | Missense Mutation (SNP) | VAF 20/199 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67649878; called by muse, mutect2
- COL6A3 | c.5218G>A p.D1740N | Missense Mutation (SNP) | VAF 16/95 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.76); catalogued as COSV55088631; called by muse, mutect2, varscan2
- COL7A1 | c.1870G>A p.A624T | Missense Mutation (SNP) | VAF 13/80 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs1459244934, COSV60394925; called by muse, mutect2, varscan2
- COL9A3 | c.794G>A p.G265D | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.638); catalogued as COSV59652589; called by muse, mutect2, varscan2
- COLEC12 | c.1295G>A p.G432D | Missense Mutation (SNP) | VAF 16/100 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as COSV68370407; called by muse, mutect2, varscan2
- COPE | c.927A>C p.*309Cext*55 | Nonstop Mutation (SNP) | VAF 11/45 reads (24%) | catalogued as COSV53230425; called by muse, mutect2, varscan2
- CPAMD8 | c.3153dup p.H1052Afs*30 (on ENST00000651564; = p.H1005Afs*30 on NM_015692.5) | Frame Shift Ins (INS) | VAF 8/44 reads (18%) | catalogued as rs750161916; called by mutect2, varscan2
- CPLANE1 | c.9142C>T p.P3048S | Missense Mutation (SNP) | VAF 16/90 reads (18%) | SIFT tolerated (0.41); PolyPhen benign (0.009); catalogued as COSV57059261; called by muse, mutect2, varscan2
- CPQ | c.745G>T p.G249W | Missense Mutation (SNP) | VAF 14/96 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55158077; called by muse, mutect2, varscan2
- CPXCR1 | c.241C>T p.R81* | Nonsense Mutation (SNP) | VAF 22/74 reads (30%) | catalogued as rs753571924, COSV52160820; called by muse, mutect2, varscan2
- CPZ | c.824G>A p.R275H (on ENST00000360986 / NM_001014447.3; = p.R264H on NM_003652.3) | Missense Mutation (SNP) | VAF 18/102 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs749063388, COSV59921949; called by muse, mutect2, varscan2
- CRACDL | c.426del p.L143Ffs*11 | Frame Shift Del (DEL) | VAF 18/102 reads (18%) | catalogued as COSV67409844; called by mutect2, pindel, varscan2
- CRAT | c.1535G>A p.R512H | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs755511310, COSV58877004; called by muse, mutect2, varscan2
- CRHBP | c.878G>A p.R293H | Missense Mutation (SNP) | VAF 16/101 reads (16%) | SIFT deleterious (0.05); PolyPhen benign (0.109); catalogued as rs78407170, COSV57188473; called by muse, mutect2, varscan2
- CRIM1 | c.2936C>A p.P979H | Missense Mutation (SNP) | VAF 24/137 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.72); catalogued as COSV54863623; called by muse, mutect2, varscan2
- CRNN | c.1195G>T p.V399L | Missense Mutation (SNP) | VAF 29/157 reads (18%) | SIFT tolerated (0.17); PolyPhen benign (0.084); catalogued as COSV55121900; called by muse, mutect2, varscan2
- CRPPA | c.590G>A p.G197D | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.688); catalogued as COSV67905841; called by muse, mutect2, varscan2
- CRY2 | c.1625G>T p.G542V | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.203); catalogued as COSV101314615; called by muse, mutect2
- CRYBG2 | c.3138G>A p.M1046I | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.01); catalogued as rs1280213163, COSV57485912; called by mutect2, varscan2
- CSGALNACT2 | c.431G>T p.G144V | Missense Mutation (SNP) | VAF 16/89 reads (18%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.666); catalogued as COSV65675549; called by muse, mutect2, varscan2
- CSMD1 | c.5705C>T p.A1902V (on ENST00000520002; = p.A1901V on NM_033225.6) | Missense Mutation (SNP) | VAF 6/94 reads (6%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.996); catalogued as COSV100153083; called by muse, mutect2
- CSMD3 | c.6137-2A>G p.X2046_splice (on ENST00000297405 / NM_001363185.1; = p.X1942_splice on NM_052900.3) | Splice Site (SNP) | VAF 9/81 reads (11%) | catalogued as COSV52173343; called by muse, mutect2, varscan2
- CSPG4 | c.2644T>G p.Y882D | Missense Mutation (SNP) | VAF 11/97 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.014); catalogued as COSV57894700; called by muse, mutect2, varscan2
- CST1 | c.241del p.V81* | Frame Shift Del (DEL) | VAF 15/143 reads (10%) | catalogued as rs756924682; called by mutect2, pindel, varscan2
- CTDP1 | c.1876G>A p.V626M | Missense Mutation (SNP) | VAF 6/61 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs761839272, COSV50001451; called by muse, mutect2
- CUBN | c.721-1G>A p.X241_splice | Splice Site (SNP) | VAF 6/43 reads (14%) | catalogued as COSV64715101; called by muse, mutect2, varscan2
- CUL2 | c.745C>T p.R249* | Nonsense Mutation (SNP) | VAF 14/52 reads (27%) | catalogued as COSV66078252; called by muse, mutect2, varscan2
- CUX2 | c.1592G>A p.G531D | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT tolerated (0.16); PolyPhen benign (0.102); catalogued as COSV55631274; called by muse, mutect2
- CXXC1 | c.785C>T p.A262V | Missense Mutation (SNP) | VAF 34/113 reads (30%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs1364204306, COSV53274448; called by muse, mutect2, varscan2
- CYB5R2 | c.433del p.T145Hfs*8 | Frame Shift Del (DEL) | VAF 8/52 reads (15%) | catalogued as rs775988957; called by mutect2, varscan2
- CYFIP2 | c.3790C>T p.R1264C (on ENST00000616178 / NM_001291722.2; = p.R1239C on NM_014376.4) | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as rs371399881; called by muse, mutect2, varscan2
- CYP11B1 | c.1075A>G p.T359A | Missense Mutation (SNP) | VAF 14/106 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0.078); catalogued as COSV52826908; called by muse, mutect2, varscan2
- CYP26C1 | c.1433G>A p.R478H | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.959); catalogued as rs756334431, CM130550, COSV53652453; called by mutect2, varscan2
- CYP39A1 | c.17C>T p.P6L | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as COSV51493391, COSV51495437; called by muse, mutect2, varscan2
- CYP3A43 | c.1009G>A p.A337T | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT tolerated (0.45); PolyPhen benign (0.011); catalogued as rs771535128, COSV55935203; called by muse, mutect2, varscan2
- CYP4B1 | c.733C>T p.R245C | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0.081); catalogued as rs200200785, COSV54721633; called by mutect2, varscan2
- CYP4F3 | c.1189G>A p.A397T | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT tolerated (0.27); PolyPhen benign (0.021); catalogued as COSV55409579; called by muse, mutect2, varscan2
- CYTIP | c.592C>T p.Q198* | Nonsense Mutation (SNP) | VAF 11/51 reads (22%) | catalogued as COSV51633653; called by muse, mutect2, varscan2
- DBH | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.026); catalogued as COSV55040773, COSV99708119; called by muse, mutect2, varscan2
- DCAF11 | c.1013G>A p.R338H | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58109096; called by mutect2, varscan2
- DCAF11 | c.1586C>T p.A529V | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0); catalogued as COSV58109104; called by muse, mutect2, varscan2
- DCAF4L2 | c.515G>A p.R172H | Missense Mutation (SNP) | VAF 15/78 reads (19%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as rs1158634102, COSV60478459; called by muse, mutect2, varscan2
- DCAF8 | c.1700G>T p.G567V | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV58783643; called by muse, mutect2, varscan2
- DCAKD | c.230C>A p.P77H | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.468); catalogued as COSV60202227; called by muse, mutect2, varscan2
- DCDC2 | c.898T>C p.S300P | Missense Mutation (SNP) | VAF 18/89 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as COSV65831817; called by muse, mutect2, varscan2
- DCLK2 | c.2214del p.T739Pfs*161 | Frame Shift Del (DEL) | VAF 10/41 reads (24%) | catalogued as COSV56205339; called by mutect2, pindel, varscan2
- DCLK3 | c.1811C>T p.A604V | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV69363078; called by muse, mutect2, varscan2
- DCSTAMP | c.269G>T p.G90V | Missense Mutation (SNP) | VAF 11/101 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV52577534; called by muse, mutect2, varscan2
- DCTN4 | c.154C>T p.P52S | Missense Mutation (SNP) | VAF 18/124 reads (15%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.997); catalogued as rs1311179419, COSV101437581; called by muse, varscan2
- DDX10 | c.857C>T p.A286V | Missense Mutation (SNP) | VAF 9/105 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.05); catalogued as COSV59434421; called by muse, mutect2
- DDX19A | c.773G>A p.R258H | Missense Mutation (SNP) | VAF 13/97 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.05); catalogued as COSV56359782; called by muse, mutect2, varscan2
- DDX60L | c.2432G>A p.R811H | Missense Mutation (SNP) | VAF 23/100 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.679); catalogued as rs747532164, COSV52709546; called by muse, mutect2, varscan2
- DGCR2 | c.839A>G p.D280G | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT tolerated (0.16); PolyPhen benign (0.006); catalogued as COSV99593935; called by muse, mutect2, varscan2
- DGKH | c.2101C>A p.P701T | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT tolerated (0.57); PolyPhen benign (0.001); catalogued as COSV54941869, COSV99819488; called by mutect2, varscan2
- DHRS1 | c.824A>G p.Y275C | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.94); catalogued as rs372828362; called by muse, mutect2, varscan2
- DHX35 | c.2012C>T p.A671V | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT tolerated (0.89); PolyPhen benign (0.001); catalogued as COSV99327267; called by muse, mutect2, varscan2
- DHX36 | c.82G>T p.G28W | Missense Mutation (SNP) | VAF 14/137 reads (10%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.996); catalogued as COSV100273545, COSV57672558, COSV57674293; called by muse, mutect2
- DHX38 | c.1085G>A p.R362H | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.943); catalogued as rs138115620; called by muse, mutect2, varscan2
- DICER1 | c.4849C>A p.L1617I | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT tolerated (0.44); PolyPhen benign (0.01); catalogued as COSV58619476; called by muse, mutect2, varscan2
- DIDO1 | c.6258G>T p.R2086S | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.605); catalogued as COSV56621589; called by muse, mutect2
- DIDO1 | c.2227C>T p.R743C | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV56615797; called by muse, mutect2, varscan2
- DIP2C | c.893A>G p.E298G | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV99793533; called by muse, mutect2, varscan2
- DIPK2A | c.970G>A p.E324K | Missense Mutation (SNP) | VAF 13/88 reads (15%) | SIFT tolerated (1); PolyPhen probably damaging (0.953); catalogued as COSV59857237; called by muse, mutect2, varscan2
- DISP1 | c.2287C>T p.R763C | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs759714329, COSV52658475; called by muse, mutect2, varscan2
- DISP2 | c.3315C>A p.F1105L | Missense Mutation (SNP) | VAF 22/126 reads (17%) | SIFT tolerated (0.05); PolyPhen benign (0.274); catalogued as COSV51121326; called by muse, mutect2, varscan2
- DISP3 | c.662C>T p.P221L | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV53826701; called by muse, mutect2, varscan2
- DLGAP1 | c.1822G>A p.A608T | Missense Mutation (SNP) | VAF 15/128 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.125); catalogued as rs994546079, COSV59784341; called by muse, mutect2, varscan2
- DLGAP3 | c.2488C>A p.L830M | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.841); catalogued as COSV52393831; called by muse, mutect2, varscan2
- DMRTB1 | c.581G>A p.R194H | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs370607830; called by mutect2, varscan2
- DNAAF1 | c.1318G>T p.G440W | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV57577141, COSV57578987; called by muse, mutect2, varscan2
- DNAH1 | c.8047C>T p.R2683W | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs779766452, COSV70228750; called by muse, mutect2, varscan2
- DNAH10 | c.6892G>A p.A2298T (on ENST00000409039; = p.A2237T on NM_207437.3) | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1375839112, COSV68993194, COSV68993911; called by muse, mutect2, varscan2
- DNAH11 | c.8035G>T p.G2679C | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT tolerated (0.74); PolyPhen possibly damaging (0.89); catalogued as COSV60954658; called by muse, mutect2, varscan2
- DNAH2 | c.6348+1G>A p.X2116_splice | Splice Site (SNP) | VAF 5/19 reads (26%) | catalogued as COSV66719260; called by mutect2, varscan2
- DNAH9 | c.10479-1G>A p.X3493_splice | Splice Site (SNP) | VAF 7/70 reads (10%) | catalogued as COSV52348399; called by muse, mutect2, varscan2
- DNAJC14 | c.1165C>T p.R389W | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs764575025, COSV57912915; called by mutect2, varscan2
- DNAJC5 | c.193G>A p.A65T | Missense Mutation (SNP) | VAF 14/85 reads (16%) | SIFT tolerated (0.23); PolyPhen benign (0.015); catalogued as rs772453351, COSV62671555; called by muse, mutect2, varscan2
- DNMBP | c.1304G>T p.G435V | Missense Mutation (SNP) | VAF 15/89 reads (17%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.058); catalogued as COSV60624730; called by muse, mutect2, varscan2
- DNMT3A | c.274G>A p.D92N | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.811); catalogued as COSV53051446; called by muse, mutect2, varscan2
- DNTTIP1 | c.373-2A>G p.X125_splice | Splice Site (SNP) | VAF 13/114 reads (11%) | catalogued as COSV65460872; called by muse, mutect2, varscan2
- DNTTIP2 | c.956A>C p.Q319P | Missense Mutation (SNP) | VAF 17/109 reads (16%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.564); catalogued as COSV63284020; called by muse, mutect2
- DOCK2 | c.1482G>T p.K494N | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.792); catalogued as COSV56956854; called by muse, mutect2, varscan2
- DOCK9 | c.5984C>T p.A1995V (on ENST00000376460 / NM_001366676.2; = p.A1996V on NM_015296.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/145 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs754298254, COSV100240827; called by muse, mutect2, varscan2
- DPYSL3 | c.1240C>T p.P414S | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.174); catalogued as COSV58326560; called by muse, mutect2, varscan2
- DRG1 | c.250C>A p.L84M | Missense Mutation (SNP) | VAF 37/278 reads (13%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.511); catalogued as COSV58918654; called by muse, mutect2, varscan2
- DSCAM | c.5060C>T p.T1687M | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.919); catalogued as rs1388489210, COSV68026232; called by muse, mutect2, varscan2
- DSPP | c.2867G>A p.S956N | Missense Mutation (SNP) | VAF 41/220 reads (19%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.036); catalogued as rs1282804206, COSV56810220; called by muse, mutect2, varscan2
- DST | c.20396C>T p.A6799V (on ENST00000361203 / NM_001374722.1; = p.A4496V on NM_015548.5) | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.915); catalogued as COSV55012979; called by muse, mutect2, varscan2
- DTL | c.1171A>G p.N391D | Missense Mutation (SNP) | VAF 9/83 reads (11%) | SIFT tolerated (0.45); PolyPhen benign (0.001); catalogued as COSV65342299; called by muse, mutect2, varscan2
- DUSP15 | c.158C>T p.A53V (on ENST00000278979 / NM_001320479.1; = p.A56V on NM_080611.4) | Missense Mutation (SNP) | VAF 12/83 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0.161); catalogued as COSV54066106; called by muse, mutect2, varscan2
- DVL2 | c.229C>T p.R77C | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.959); catalogued as rs758501117, COSV50034603; called by mutect2, varscan2
- DYNC1I2 | c.49C>T p.R17* | Nonsense Mutation (SNP) | VAF 20/192 reads (10%) | catalogued as rs540814246, COSV99784279; called by muse, mutect2, varscan2
- DYNC1I2 | c.1900A>G p.T634A | Missense Mutation (SNP) | VAF 33/176 reads (19%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as COSV99784281; called by muse, mutect2, varscan2
- DYNC2H1 | c.91C>T p.P31S | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT tolerated (0.54); PolyPhen benign (0.003); catalogued as COSV100519595; called by muse, mutect2, varscan2
- EARS2 | c.1270C>A p.L424M | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs1261148278, COSV71942830; called by muse, mutect2, varscan2
- ECHDC2 | c.584G>A p.R195Q (on ENST00000371522 / NM_001198961.2; = p.R164Q on NM_018281.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.159); catalogued as rs757348200, COSV64301008; called by mutect2, varscan2
- EDC4 | c.1543G>A p.A515T | Missense Mutation (SNP) | VAF 16/110 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.388); catalogued as COSV62765985; called by muse, mutect2, varscan2
- EDN3 | c.95G>T p.G32V | Missense Mutation (SNP) | VAF 11/82 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.601); catalogued as COSV61107905; called by muse, mutect2, varscan2
- EEFSEC | c.550G>A p.V184M | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs373534963, COSV54625164; called by muse, mutect2, varscan2
- EFHB | c.547A>G p.N183D | Missense Mutation (SNP) | VAF 21/109 reads (19%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.001); catalogued as COSV55547735; called by muse, mutect2, varscan2
- EFS | c.1644G>T p.Q548H | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT tolerated (0.26); PolyPhen benign (0.023); catalogued as COSV99249027; called by muse, mutect2
- EGFLAM | c.1937G>A p.G646E | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as COSV100380702; called by muse, mutect2, varscan2
- EGFR | c.3287C>T p.S1096F | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV51794983; called by muse, mutect2, varscan2
- EGLN2 | c.1199T>C p.V400A | Missense Mutation (SNP) | VAF 44/120 reads (37%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.21); catalogued as COSV58279873; called by muse, mutect2, varscan2
- EGR3 | c.197C>A p.P66Q | Missense Mutation (SNP) | VAF 14/92 reads (15%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as rs777341372, COSV57833457; called by muse, mutect2, varscan2
- EIF2B5 | c.538C>T p.R180W (on ENST00000647909; = p.R172W on NM_003907.3) | Missense Mutation (SNP) | VAF 6/59 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as rs373147037; called by mutect2, varscan2
- EIF3H | c.85G>T p.G29C | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as COSV99412233; called by muse, mutect2, varscan2
- EIF4B | c.265C>A p.R89S | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.503); catalogued as COSV50402825; called by muse, mutect2, varscan2
- ELAPOR1 | c.1721C>A p.S574Y | Missense Mutation (SNP) | VAF 18/204 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1450612646, COSV64040378; called by muse, mutect2
- ELOVL2 | c.202C>T p.L68F | Missense Mutation (SNP) | VAF 9/88 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV61155057; called by muse, mutect2, varscan2
- ELOVL4 | c.937G>T p.G313* | Nonsense Mutation (SNP) | VAF 35/296 reads (12%) | catalogued as COSV63953827; called by muse, mutect2, varscan2
- EMC1 | c.713C>A p.P238H | Missense Mutation (SNP) | VAF 12/88 reads (14%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.75); catalogued as COSV61886984; called by muse, mutect2, varscan2
- EMC9 | c.121C>A p.L41M | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.925); catalogued as COSV52824137; called by muse, mutect2, varscan2
- EMILIN1 | c.1328G>A p.R443Q | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT tolerated (0.58); PolyPhen benign (0.003); catalogued as rs766813380, COSV53154751; called by muse, mutect2
- ENPP3 | c.1208C>T p.A403V | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.911); catalogued as rs1276713826, COSV62954163; called by muse, mutect2, varscan2
- ENPP5 | c.1171T>C p.S391P | Missense Mutation (SNP) | VAF 8/83 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV57908623; called by muse, mutect2, varscan2
- EPB41L1 | c.1222G>A p.A408T | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.733); catalogued as rs978010310, COSV52437534; called by muse, mutect2
- EPB41L2 | c.2009G>A p.R670Q | Missense Mutation (SNP) | VAF 26/129 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs751011583, COSV100441337; called by muse, mutect2, varscan2
- EPB41L3 | c.1813T>A p.Y605N | Missense Mutation (SNP) | VAF 30/184 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59452553; called by muse, mutect2, varscan2
- EPB41L3 | c.1274G>A p.R425H | Missense Mutation (SNP) | VAF 25/204 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs1350949619, COSV59447862; called by muse, mutect2, varscan2
- EPHA3 | c.2306G>A p.R769H | Missense Mutation (SNP) | VAF 21/121 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV60692736, COSV60699595; called by muse, mutect2, varscan2
- EPS8L2 | c.1093C>T p.R365C | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as rs746329487, COSV59347866; called by mutect2, varscan2
- ERBB4 | c.317G>A p.R106H | Missense Mutation (SNP) | VAF 15/83 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs991337964, COSV53530091; called by muse, mutect2, varscan2
- ERF | c.1259C>T p.P420L | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.099); catalogued as COSV55895791; called by muse, mutect2, varscan2
- ERICH1 | c.835G>T p.E279* | Nonsense Mutation (SNP) | VAF 12/78 reads (15%) | catalogued as COSV50638178; called by muse, mutect2, varscan2
- ESPL1 | c.3146C>T p.S1049L | Missense Mutation (SNP) | VAF 17/94 reads (18%) | SIFT tolerated (0.68); PolyPhen benign (0.003); catalogued as rs575347377, COSV57757204; called by muse, mutect2, varscan2
- ETNPPL | c.14A>G p.Y5C | Missense Mutation (SNP) | VAF 12/88 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.566); catalogued as COSV56595674; called by muse, varscan2
- ETV1 | c.1372G>A p.A458T | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as COSV54142094; called by muse, mutect2
- ETV7 | c.38C>A p.P13H | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.62); catalogued as COSV100339307; called by muse, mutect2
- EXOC7 | c.872A>G p.K291R | Missense Mutation (SNP) | VAF 10/100 reads (10%) | SIFT tolerated (0.33); PolyPhen benign (0.007); catalogued as COSV58739227; called by muse, varscan2
- EXOSC9 | c.1081G>A p.G361S | Missense Mutation (SNP) | VAF 11/79 reads (14%) | SIFT tolerated (0.6); PolyPhen benign (0.003); catalogued as rs148293459; called by muse, mutect2, varscan2
- EYS | c.259A>T p.I87F | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.216); catalogued as rs780162766, COSV60981106, COSV60984562; called by mutect2, varscan2
- F11 | c.1675A>T p.I559F | Missense Mutation (SNP) | VAF 22/202 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.426); catalogued as COSV99250914; called by muse, mutect2, varscan2
- F11R | c.662C>A p.P221H | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.709); catalogued as rs751059901, COSV57037420; called by mutect2, varscan2
- FADD | c.331G>C p.D111H | Missense Mutation (SNP) | VAF 17/126 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV57228968, COSV57229208; called by muse, mutect2, varscan2
- FAF1 | c.824G>A p.R275Q | Missense Mutation (SNP) | VAF 15/88 reads (17%) | SIFT tolerated (0.55); PolyPhen benign (0.001); catalogued as rs538524843, COSV65638388; called by muse, mutect2, varscan2
- FAM171A1 | c.2267G>T p.R756M | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65315836; called by muse, mutect2
- FAM171A1 | c.145G>A p.V49I | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs547476247, COSV65315842; called by muse, mutect2, varscan2
- FAM199X | c.1001G>A p.R334Q | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.947); catalogued as rs1378312753, COSV55433565; called by muse, mutect2, varscan2
- FAM222A | c.1217T>C p.L406P | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62723271; called by muse, mutect2, varscan2
- FAM228A | c.109G>T p.D37Y | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV54595336; called by muse, mutect2, varscan2
- FASN | c.427C>T p.R143W | Missense Mutation (SNP) | VAF 3/30 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60750504; called by muse, mutect2
- FBXO21 | c.791C>T p.A264V | Missense Mutation (SNP) | VAF 11/100 reads (11%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.922); catalogued as COSV57972788; called by muse, mutect2, varscan2
- FBXO33 | c.1445G>C p.G482A | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99981031; called by muse, mutect2, varscan2
- FBXO9 | c.33G>T p.Q11H | Missense Mutation (SNP) | VAF 33/194 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.948); catalogued as COSV55055697; called by muse, mutect2, varscan2
- FBXW11 | c.1480C>T p.R494C | Missense Mutation (SNP) | VAF 13/92 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.627); catalogued as rs1265464557, COSV51608891; called by muse, mutect2, varscan2
- FCHO1 | c.279G>T p.Q93H | Missense Mutation (SNP) | VAF 11/72 reads (15%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV53182444; called by muse, mutect2, varscan2
- FCHO2 | c.2405C>T p.A802V | Missense Mutation (SNP) | VAF 15/126 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.1); catalogued as COSV59272754; called by muse, mutect2, varscan2
- FCHSD1 | c.1042C>T p.R348W | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs1286655902, COSV101447613; called by muse, mutect2
- FCN3 | c.127C>A p.L43M | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); catalogued as COSV54641321; called by muse, mutect2, varscan2
- FEN1 | c.1016G>A p.R339H | Missense Mutation (SNP) | VAF 15/104 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs573495657, COSV57250794; called by muse, mutect2, varscan2
- FEZF2 | c.185A>T p.K62I | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.601); catalogued as COSV99334990; called by muse, mutect2, varscan2
- FFAR3 | c.91del p.L31Sfs*27 | Frame Shift Del (DEL) | VAF 76/342 reads (22%) | catalogued as COSV59909196, COSV59909320; called by mutect2, varscan2
- FGD2 | c.925C>A p.L309I | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.777); catalogued as COSV51463572; called by muse, mutect2, varscan2
- FGFR4 | c.1502C>T p.A501V | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV52803342; called by muse, mutect2, varscan2
- FHDC1 | c.2744C>T p.A915V | Missense Mutation (SNP) | VAF 19/106 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.053); catalogued as rs1331411088, COSV52599658; called by muse, mutect2, varscan2
- FHOD1 | c.364G>A p.A122T | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.538); catalogued as rs1413971720, COSV50758956; called by muse, mutect2, varscan2
- FIG4 | c.1190C>T p.A397V | Missense Mutation (SNP) | VAF 15/116 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.934); catalogued as COSV57787402; called by muse, mutect2, varscan2
- FIGN | c.1988T>C p.V663A | Missense Mutation (SNP) | VAF 22/181 reads (12%) | SIFT tolerated (0.62); PolyPhen benign (0.003); catalogued as COSV100292905; called by muse, mutect2, varscan2
- FKBP10 | c.1741G>T p.E581* | Nonsense Mutation (SNP) | VAF 8/46 reads (17%) | catalogued as COSV54055674; called by muse, mutect2, varscan2
- FKRP | c.1420G>T p.G474W | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1439214152, COSV59358683; called by muse, mutect2
- FLG | c.3229C>T p.H1077Y | Missense Mutation (SNP) | VAF 17/129 reads (13%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.881); catalogued as rs557910401, COSV64238309; called by muse, mutect2, varscan2
- FLI1 | c.852G>A p.W284* | Nonsense Mutation (SNP) | VAF 6/45 reads (13%) | catalogued as COSV99858085; called by muse, mutect2
- FLII | c.1570G>A p.E524K | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.85); catalogued as rs901042933, COSV58944834; called by muse, mutect2, varscan2
- FLRT1 | c.1346A>G p.D449G | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.23); catalogued as COSV55360129; called by muse, mutect2, varscan2
- FMO1 | c.413C>T p.A138V | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.744); catalogued as COSV61445651; called by muse, mutect2, varscan2
- FN1 | c.699T>A p.D233E | Missense Mutation (SNP) | VAF 7/77 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60552222; called by muse, mutect2
- FNDC1 | c.3293C>T p.A1098V | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.091); catalogued as COSV99796600; called by muse, mutect2
- FOXD4 | c.546del p.A183Pfs*141 | Frame Shift Del (DEL) | VAF 24/139 reads (17%) | catalogued as COSV58702379; called by mutect2, varscan2
- FOXD4 | c.158C>T p.P53L | Missense Mutation (SNP) | VAF 61/474 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.164); catalogued as rs751809498, COSV58700097; called by muse, mutect2, varscan2
- FOXG1 | c.484G>T p.G162C | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.284); catalogued as COSV100487040, COSV57398163; called by muse, mutect2
- FOXI1 | c.557G>A p.R186H | Missense Mutation (SNP) | VAF 17/92 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1264885315, COSV100089582, COSV60389779; called by muse, mutect2, varscan2
- FOXP1 | c.430C>T p.Q144* | Nonsense Mutation (SNP) | VAF 24/199 reads (12%) | catalogued as COSV59537573, COSV59541691; called by muse, mutect2, varscan2
- FOXRED1 | c.1118C>A p.P373Q | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.602); catalogued as COSV55006417; called by muse, mutect2, varscan2
- FRMD3 | c.1513C>T p.R505C | Missense Mutation (SNP) | VAF 10/84 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.333); catalogued as rs778524664, COSV58460976; called by muse, mutect2, varscan2
- FRYL | c.8212C>T p.R2738C | Missense Mutation (SNP) | VAF 35/180 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.856); catalogued as rs760927134, COSV51939133; called by muse, mutect2, varscan2
- FSCN1 | c.1385C>T p.A462V | Missense Mutation (SNP) | VAF 15/84 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.689); catalogued as COSV61017557; called by muse, mutect2, varscan2
- FSCN2 | c.794C>T p.A265V | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.584); catalogued as COSV100603337; called by muse, mutect2
- FZD1 | c.1315G>A p.A439T | Missense Mutation (SNP) | VAF 17/101 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55310367; called by muse, mutect2
- G2E3 | c.900A>C p.K300N | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.617); catalogued as COSV52838359, COSV52840194; called by muse, mutect2, varscan2
- G3BP1 | c.1339C>T p.R447C | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs187250945, COSV62366143; called by mutect2, varscan2
- G6PD | c.679C>T p.R227W | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1557230213, CM992890, COSV100855017; called by muse, mutect2
- GABBR1 | c.1721del p.P574Qfs*32 | Frame Shift Del (DEL) | VAF 9/63 reads (14%) | catalogued as rs777471402; called by mutect2, pindel, varscan2
- GABRA5 | c.551C>T p.A184V | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT tolerated (0.33); PolyPhen benign (0.023); catalogued as rs1479609899, COSV59479333, COSV59486857; called by muse, mutect2, varscan2
- GABRA6 | c.143G>A p.R48Q | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs751098162, COSV50883531; called by mutect2, varscan2
- GAL3ST2 | c.979G>A p.A327T | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.021); catalogued as COSV51950180; called by muse, mutect2
- GALK1 | c.508T>C p.C170R | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99849636; called by muse, mutect2
- GAPVD1 | c.1181C>A p.S394Y | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as COSV52922792; called by muse, mutect2, varscan2
- GAS2L1 | c.1839del p.P614Hfs*2 | Frame Shift Del (DEL) | VAF 8/44 reads (18%) | catalogued as rs78929040; called by mutect2, pindel, varscan2
- GBP4 | c.1027C>T p.Q343* | Nonsense Mutation (SNP) | VAF 20/91 reads (22%) | catalogued as COSV63254194; called by muse, mutect2, varscan2
- GCC1 | c.1730G>A p.R577H | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as rs374524039, COSV58461667; called by muse, mutect2, varscan2
- GCC2 | c.2135del p.L712Cfs*16 | Frame Shift Del (DEL) | VAF 34/182 reads (19%) | catalogued as rs777909420; called by mutect2, varscan2
- GID8 | c.577G>A p.A193T | Missense Mutation (SNP) | VAF 36/258 reads (14%) | SIFT tolerated (0.46); PolyPhen benign (0.105); catalogued as COSV56611429; called by muse, mutect2, varscan2
- GIGYF2 | c.2243C>T p.A748V | Missense Mutation (SNP) | VAF 47/336 reads (14%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.968); catalogued as COSV65249098; called by muse, mutect2, varscan2
- GIGYF2 | c.3407C>T p.T1136M | Missense Mutation (SNP) | VAF 14/71 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.024); catalogued as rs776246457, COSV65250862; called by muse, mutect2, varscan2
- GIPC1 | c.272G>A p.R91H | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs1394720952, COSV100600149; called by muse, mutect2, varscan2
- GIPC3 | c.367G>T p.G123W | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV59258994; called by muse, mutect2, varscan2
- GJC1 | c.1018C>T p.R340W | Missense Mutation (SNP) | VAF 20/123 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as rs767836844, COSV57911189; called by muse, mutect2, varscan2
- GLCCI1 | c.1062G>T p.Q354H | Missense Mutation (SNP) | VAF 20/76 reads (26%) | SIFT tolerated (0.16); PolyPhen benign (0.034); catalogued as rs145013590; called by muse, mutect2, varscan2
- GLI2 | c.685C>T p.R229C | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs751614251, COSV58041455; called by muse, mutect2, varscan2
- GLRA4 | c.1191T>A p.S397R | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.013); catalogued as COSV60327619; called by muse, mutect2, varscan2
- GMIP | c.871C>T p.R291* | Nonsense Mutation (SNP) | VAF 17/113 reads (15%) | catalogued as COSV52556037; called by muse, mutect2, varscan2
- GNAT1 | c.20C>T p.A7V | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.013); catalogued as rs1293986442, COSV50029446; called by muse, mutect2, varscan2
- GNS | c.698C>T p.A233V | Missense Mutation (SNP) | VAF 20/137 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs766044815, COSV50694602; called by muse, mutect2, varscan2
- GON4L | c.3923G>A p.G1308D | Missense Mutation (SNP) | VAF 10/94 reads (11%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0); catalogued as rs745602514, COSV55193179; called by mutect2, varscan2
- GPC2 | c.1666del p.A556Hfs*31 | Frame Shift Del (DEL) | VAF 6/54 reads (11%) | catalogued as rs753572388; called by pindel, varscan2
- GPD2 | c.1322G>A p.R441Q | Missense Mutation (SNP) | VAF 15/91 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs140203221, COSV60092585; called by muse, mutect2, varscan2
- GPR148 | c.327C>A p.S109R | Missense Mutation (SNP) | VAF 12/83 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.915); catalogued as COSV59308194; called by muse, mutect2, varscan2
- GPR149 | c.497C>T p.A166V | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT tolerated (0.74); PolyPhen benign (0.05); catalogued as COSV67667167; called by muse, mutect2, varscan2
- GPR88 | c.244G>A p.A82T | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.783); catalogued as COSV59291446; called by muse, mutect2, varscan2
- GPRC5C | c.201G>T p.W67C (on ENST00000652232; = p.W22C on NM_018653.4) | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.579); catalogued as COSV61236771; called by muse, mutect2, varscan2
- GPRIN3 | c.2167T>A p.L723I | Missense Mutation (SNP) | VAF 13/97 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.148); catalogued as COSV60884808; called by muse, mutect2, varscan2
- GRAMD4 | c.1148G>A p.R383H | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as rs1233779718, COSV63030250; called by muse, mutect2, varscan2
- GREM2 | c.361G>A p.A121T | Missense Mutation (SNP) | VAF 9/77 reads (12%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.914); catalogued as COSV58946484; called by muse, mutect2, varscan2
- GRIN3B | c.2591G>A p.R864H | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52260131; called by muse, mutect2
- GRIP2 | c.2515C>A p.L839I (on ENST00000619221; = p.L742I on NM_001080423.4) | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT tolerated (0.44); PolyPhen benign (0.381); catalogued as COSV99817622; called by muse, mutect2, varscan2
- GRIP2 | c.949C>T p.R317W (on ENST00000619221; = p.R220W on NM_001080423.4) | Missense Mutation (SNP) | VAF 10/84 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as rs755847798, COSV99817624; called by mutect2, varscan2
- GSAP | c.1157C>A p.P386H | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.891); catalogued as COSV57529822; called by muse, mutect2, varscan2
- GSC | c.385T>C p.S129P | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as COSV99450344; called by muse, mutect2
- GSE1 | c.70G>A p.A24T | Missense Mutation (SNP) | VAF 14/105 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1031374034, COSV53671842, COSV53675231; called by muse, mutect2, varscan2
- GTF2B | c.146G>T p.G49V | Missense Mutation (SNP) | VAF 16/123 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as COSV100980568; called by muse, mutect2, varscan2
- GTF3C1 | c.3266G>A p.R1089H | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.73); catalogued as rs1167472934, COSV62241085; called by muse, mutect2, varscan2
- H2AC11 | c.359del p.K120Rfs*16 | Frame Shift Del (DEL) | VAF 21/184 reads (11%) | catalogued as COSV60361927; called by mutect2, pindel, varscan2
- H2AC6 | c.115A>G p.N39D | Missense Mutation (SNP) | VAF 10/106 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.829); catalogued as COSV58415984; called by mutect2, varscan2
- H6PD | c.1270C>T p.P424S | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.034); catalogued as COSV66230975; called by muse, mutect2
- HARS2 | c.1087C>T p.R363C | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1051862023, COSV51226930; called by muse, mutect2, varscan2
- HASPIN | c.2227C>T p.L743F | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.708); catalogued as COSV99561480; called by muse, mutect2, varscan2
- HCN3 | c.912G>T p.K304N | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.644); catalogued as COSV100855790; called by muse, mutect2, varscan2
- HCN4 | c.2471G>T p.R824M | Missense Mutation (SNP) | VAF 5/55 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.496); catalogued as COSV56083412; called by muse, mutect2
- HCST | c.139_140del p.L47Afs*10 | Frame Shift Del (DEL) | VAF 26/82 reads (32%) | catalogued as rs1391552111; called by pindel, varscan2
- HDAC11 | c.595T>C p.Y199H | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.706); catalogued as COSV99850047; called by muse, mutect2, varscan2
- HDAC4 | c.1868G>A p.G623D | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.279); catalogued as COSV61864899; called by muse, mutect2, varscan2
- HDGFL2 | c.1487G>A p.C496Y | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.154); catalogued as COSV56682706; called by muse, mutect2, varscan2
- HDHD5 | c.678del p.Y227Tfs*7 (on ENST00000336737 / NM_033070.3; = p.Y197Tfs*7 on NM_017829.5) | Frame Shift Del (DEL) | VAF 11/77 reads (14%) | catalogued as rs760251393; called by mutect2, pindel, varscan2
- HECW1 | c.1409C>T p.A470V | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.01); catalogued as COSV67828833; called by muse, mutect2, varscan2
- HEG1 | c.3313del p.S1105Qfs*21 | Frame Shift Del (DEL) | VAF 8/72 reads (11%) | catalogued as rs1374777360; called by mutect2, pindel
- HELZ2 | c.5801G>A p.R1934Q (on ENST00000467148 / NM_001037335.2; = p.R1365Q on NM_033405.3) | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT tolerated (0.47); PolyPhen benign (0.001); catalogued as rs200467624; called by mutect2, varscan2
- HEPACAM2 | c.831del p.N278Tfs*22 (on ENST00000394468 / NM_001039372.4; = p.N266Tfs*22 on NM_198151.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 13/91 reads (14%) | catalogued as rs1299788313; called by mutect2, pindel, varscan2
- HERC1 | c.7832G>T p.G2611V | Missense Mutation (SNP) | VAF 21/88 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.04); catalogued as COSV71247711; called by muse, mutect2, varscan2
- HERC2 | c.11816G>T p.R3939M | Missense Mutation (SNP) | VAF 14/112 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV55344464, COSV99876468; called by muse, mutect2, varscan2
- HGH1 | c.983G>A p.R328Q | Missense Mutation (SNP) | VAF 26/132 reads (20%) | SIFT tolerated (0.68); PolyPhen benign (0.015); catalogued as rs1434231638; called by muse, mutect2, varscan2
- HIF1A | c.1135G>A p.E379K | Missense Mutation (SNP) | VAF 13/90 reads (14%) | SIFT tolerated (0.7); PolyPhen benign (0.04); catalogued as COSV60189174; called by muse, mutect2, varscan2
- HIGD1C | c.277A>C p.S93R | Missense Mutation (SNP) | VAF 14/130 reads (11%) | SIFT tolerated (0.22); PolyPhen benign (0.015); catalogued as rs1231804978, COSV68250655; called by muse, mutect2, varscan2
- HIP1R | c.3139G>A p.A1047T | Missense Mutation (SNP) | VAF 9/90 reads (10%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV53439697, COSV53441405; called by muse, mutect2
- HIPK1 | c.940G>A p.A314T | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV65784440; called by muse, mutect2, varscan2
- HIRA | c.2071G>A p.A691T | Missense Mutation (SNP) | VAF 16/100 reads (16%) | SIFT tolerated (0.5); PolyPhen benign (0.001); catalogued as COSV54274705; called by muse, mutect2, varscan2
- HLTF | c.1858C>T p.R620C | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100027093; called by muse, mutect2, varscan2
- HMGCR | c.1650A>T p.E550D | Missense Mutation (SNP) | VAF 22/91 reads (24%) | SIFT tolerated (0.54); PolyPhen benign (0.003); catalogued as COSV55315513; called by muse, mutect2, varscan2
- HNRNPL | c.1010dup p.P338Tfs*56 | Frame Shift Ins (INS) | VAF 16/66 reads (24%) | catalogued as rs767148651; called by mutect2, varscan2
- HNRNPUL1 | c.2239G>A p.V747I | Missense Mutation (SNP) | VAF 24/202 reads (12%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); catalogued as rs756288660, COSV54562064; called by muse, mutect2, varscan2
- HOXA2 | c.692C>T p.T231M | Missense Mutation (SNP) | VAF 29/189 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.146); catalogued as rs991740115, COSV56066217; called by muse, mutect2, varscan2
- HOXB3 | c.750G>T p.K250N | Missense Mutation (SNP) | VAF 13/74 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.134); catalogued as COSV57486730, COSV57487939; called by muse, mutect2, varscan2
- HR | c.2446C>T p.P816S | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.994); catalogued as COSV57191900; called by muse, mutect2, varscan2
- HRC | c.984G>T p.E328D | Missense Mutation (SNP) | VAF 32/306 reads (10%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.683); catalogued as COSV53256146; called by muse, mutect2, varscan2
- HSF2 | c.1577C>A p.P526H | Missense Mutation (SNP) | VAF 17/79 reads (22%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.921); catalogued as COSV63773869; called by muse, mutect2, varscan2
- HSP90B1 | c.1502C>T p.S501L | Missense Mutation (SNP) | VAF 27/248 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.931); catalogued as rs1441073648, COSV55358665; called by muse, mutect2, varscan2
- HSPA1L | c.1480G>A p.D494N | Missense Mutation (SNP) | VAF 41/227 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.999); catalogued as COSV65150468; called by muse, mutect2, varscan2
- HTATSF1 | c.949G>A p.V317M | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); catalogued as COSV54478781; called by muse, mutect2, varscan2
- HTR1B | c.889G>A p.A297T | Missense Mutation (SNP) | VAF 11/81 reads (14%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.488); catalogued as rs200757538, COSV64051434; called by muse, mutect2, varscan2
- HTR1B | c.619C>T p.L207F | Missense Mutation (SNP) | VAF 9/78 reads (12%) | SIFT tolerated (0.63); PolyPhen benign (0.026); catalogued as COSV64051437; called by muse, mutect2, varscan2
- HTR1E | c.569C>T p.A190V | Missense Mutation (SNP) | VAF 16/99 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs755175910, COSV59507423; called by muse, mutect2, varscan2
- HTRA1 | c.1297G>A p.V433I | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT tolerated (0.46); PolyPhen benign (0.13); catalogued as rs751200867, COSV64563953; called by muse, mutect2, varscan2
- IARS2 | c.1598C>A p.P533H | Missense Mutation (SNP) | VAF 22/91 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56959612; called by muse, mutect2, varscan2
- IFFO1 | c.898G>A p.E300K | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.754); catalogued as COSV60737476; called by muse, mutect2, varscan2
- IFNAR2 | c.909G>T p.E303D | Missense Mutation (SNP) | VAF 5/54 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.164); catalogued as COSV51615310; called by muse, mutect2, varscan2
- IFNL1 | c.444C>A p.H148Q | Missense Mutation (SNP) | VAF 13/105 reads (12%) | SIFT tolerated (0.24); PolyPhen benign (0.012); catalogued as COSV61317719; called by muse, mutect2, varscan2
- IFT88 | c.1226+1G>A p.X409_splice (on ENST00000319980 / NM_001318493.2; = p.X400_splice on NM_006531.5 and 9 other RefSeq transcripts) | Splice Site (SNP) | VAF 8/35 reads (23%) | catalogued as COSV60673115; called by muse, mutect2, varscan2
- IGF2BP1 | c.592del p.L198Ffs*32 | Frame Shift Del (DEL) | VAF 4/28 reads (14%) | catalogued as COSV51736634; called by pindel, varscan2
- IGF2BP2 | c.1535C>T p.A512V | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT tolerated (0.7); PolyPhen possibly damaging (0.531); catalogued as rs528084524, COSV60485738; called by muse, mutect2, varscan2
- IGF2R | c.3488C>T p.A1163V | Missense Mutation (SNP) | VAF 14/105 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.045); catalogued as rs780352875, COSV63628896; called by muse, mutect2, varscan2
- IGSF9 | c.154dup p.L52Pfs*27 | Frame Shift Ins (INS) | VAF 13/49 reads (27%) | catalogued as rs753928344; called by mutect2, varscan2
- IL10RA | c.383G>A p.G128D | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as rs748186383, COSV57140473; called by muse, mutect2, varscan2
- IL1B | c.738G>A p.M246I | Missense Mutation (SNP) | VAF 22/161 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.154); catalogued as COSV54521633; called by muse, mutect2, varscan2
- IL2RB | c.1249G>A p.A417T | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.539); catalogued as rs768345015, COSV53426180; called by mutect2, varscan2
- IMPA2 | c.313G>A p.G105S | Missense Mutation (SNP) | VAF 3/30 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs988651206, COSV52319551; called by muse, mutect2
- IMPDH2 | c.670C>T p.R224W | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs377463111; called by muse, mutect2, varscan2
- INAVA | c.1268G>A p.R423H | Missense Mutation (SNP) | VAF 21/162 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs201281905; called by muse, mutect2, varscan2
- INHBC | c.862C>T p.P288S | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.947); catalogued as COSV59005039; called by muse, mutect2, varscan2
- INTS10 | c.2012T>C p.V671A | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT tolerated (0.21); PolyPhen benign (0.143); catalogued as COSV67604145; called by muse, mutect2, varscan2
- INTS11 | c.772C>T p.R258C | Missense Mutation (SNP) | VAF 10/84 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs199864556, COSV60088247; called by mutect2, varscan2
- INTS2 | c.1414G>A p.V472I | Missense Mutation (SNP) | VAF 18/114 reads (16%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.931); catalogued as rs879053030, COSV52153035; called by muse, mutect2, varscan2
- INTS2 | c.932C>T p.A311V | Missense Mutation (SNP) | VAF 26/156 reads (17%) | SIFT tolerated (0.29); PolyPhen benign (0.042); catalogued as rs370336239; called by muse, mutect2, varscan2
- INTU | c.1772del p.L591Cfs*2 | Frame Shift Del (DEL) | VAF 13/90 reads (14%) | catalogued as COSV58874688; called by mutect2, pindel, varscan2
- IQGAP3 | c.797A>G p.H266R | Missense Mutation (SNP) | VAF 16/109 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1293448615, COSV63251270; called by muse, mutect2, varscan2
- IRX6 | c.136G>A p.A46T | Missense Mutation (SNP) | VAF 10/83 reads (12%) | SIFT tolerated (0.42); PolyPhen benign (0.022); catalogued as rs1161197805, COSV51860702; called by muse, mutect2, varscan2
- ITGA5 | c.101C>T p.P34L | Missense Mutation (SNP) | VAF 30/117 reads (26%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as rs756815283, COSV53216035; called by muse, mutect2, varscan2
- ITGB5 | c.1019dup p.N340Kfs*34 | Frame Shift Ins (INS) | VAF 28/156 reads (18%) | catalogued as rs763839738; called by mutect2, pindel, varscan2
- ITIH1 | c.838T>A p.F280I | Missense Mutation (SNP) | VAF 20/149 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56254782; called by muse, mutect2, varscan2
- JAG1 | c.767G>A p.G256D | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54756460; called by muse, mutect2
- JAG2 | c.2968G>A p.A990T | Missense Mutation (SNP) | VAF 13/102 reads (13%) | SIFT tolerated (0.31); PolyPhen benign (0.011); catalogued as rs766346968, COSV59308794; called by mutect2, varscan2
- JAK1 | c.1139C>A p.S380Y | Missense Mutation (SNP) | VAF 39/200 reads (20%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.459); catalogued as COSV61090741, COSV61091414; called by muse, mutect2, varscan2
- JMY | c.1944T>A p.Y648* | Nonsense Mutation (SNP) | VAF 30/255 reads (12%) | catalogued as COSV101268102; called by muse, varscan2
- JPH3 | c.1432C>T p.Q478* | Nonsense Mutation (SNP) | VAF 10/37 reads (27%) | catalogued as COSV52467367; called by muse, mutect2
- JUN | c.198_199insT p.G67Wfs*40 | Frame Shift Ins (INS) | VAF 21/118 reads (18%) | catalogued as COSV64664458; called by mutect2, pindel, varscan2
- KALRN | c.3370C>T p.R1124W | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1245112892, COSV53762859; called by muse, mutect2, varscan2
- KANK1 | c.1876C>T p.R626W | Missense Mutation (SNP) | VAF 26/87 reads (30%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); catalogued as rs986771749, COSV63209808; called by muse, mutect2, varscan2
- KCNA1 | c.1046C>T p.A349V | Missense Mutation (SNP) | VAF 26/223 reads (12%) | SIFT tolerated (0.4); PolyPhen benign (0.014); catalogued as rs1361446640, COSV66836423, COSV66837186; called by muse, mutect2, varscan2
- KCNA6 | c.1052G>A p.R351H | Missense Mutation (SNP) | VAF 11/87 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54975092; called by muse, mutect2, varscan2
- KCNA6 | c.1276G>A p.G426R | Missense Mutation (SNP) | VAF 27/170 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54974736; called by muse, mutect2, varscan2
- KCNC3 | c.1267C>T p.R423C | Missense Mutation (SNP) | VAF 16/118 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65387315; called by muse, varscan2
- KCND2 | c.5C>T p.A2V | Missense Mutation (SNP) | VAF 17/114 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as rs768046279, COSV58571630; called by muse, mutect2, varscan2
- KCNH2 | c.2201G>A p.R734H | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV51139400; called by muse, mutect2, varscan2
- KCNJ5 | c.616G>A p.A206T | Missense Mutation (SNP) | VAF 11/82 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs750424299, COSV57965763; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KCNK10 | c.366G>T p.Q122H | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT tolerated (0.14); PolyPhen benign (0.212); catalogued as COSV56644298; called by muse, mutect2
- KCNK18 | c.892G>A p.A298T | Missense Mutation (SNP) | VAF 19/140 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV57971699; called by muse, mutect2, varscan2
- KCNQ3 | c.2500G>A p.A834T | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs772240164, COSV66463681; called by mutect2, varscan2
- KCNS2 | c.445G>A p.D149N | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.685); catalogued as rs866829393, COSV54637340; called by muse, mutect2, varscan2
- KDM5A | c.4170G>A p.M1390I | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.838); catalogued as rs759172420, COSV66992252; called by muse, mutect2, varscan2
- KHSRP | c.1988del p.G663Vfs*60 | Frame Shift Del (DEL) | VAF 5/42 reads (12%) | catalogued as COSV67919765; called by mutect2, pindel
- KIAA0930 | c.161A>T p.Y54F (on ENST00000336156 / NM_001009880.2; = p.Y59F on NM_015264.2) | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.857); catalogued as COSV52663136; called by muse, mutect2, varscan2
- KIAA1109 | c.6749C>T p.A2250V | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.001); catalogued as COSV99174048; called by muse, mutect2, varscan2
- KIAA1586 | c.619del p.I207Lfs*17 | Frame Shift Del (DEL) | VAF 13/52 reads (25%) | catalogued as rs746314511; called by mutect2, varscan2
- KIDINS220 | c.1142G>A p.R381Q | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1286682721, COSV56753178, COSV99875851; called by muse, mutect2, varscan2
- KIF21A | c.3950C>T p.S1317F (on ENST00000361418 / NM_001378440.1; = p.S1304F on NM_017641.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.015); catalogued as rs781410152, COSV62766877; called by mutect2, varscan2
- KIF25 | c.869C>T p.A290V | Missense Mutation (SNP) | VAF 14/77 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.005); catalogued as rs779727454, COSV63027318; called by muse, mutect2, varscan2
- KIF7 | c.3062G>A p.R1021H | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as rs1416932636, COSV51541199; called by muse, mutect2, varscan2
- KIRREL3 | c.368C>T p.A123V | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs867594856, COSV101585867; called by muse, mutect2, varscan2
- KLB | c.1619C>T p.A540V | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.76); PolyPhen benign (0.007); catalogued as COSV99962444; called by muse, mutect2
- KLC1 | c.218G>A p.R73Q | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT tolerated (0.28); PolyPhen benign (0.005); catalogued as rs767453920, COSV55807800; called by mutect2, varscan2
- KLC3 | c.250G>A p.E84K | Missense Mutation (SNP) | VAF 35/107 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.647); catalogued as rs769289827, COSV67278685; called by muse, mutect2, varscan2
- KLF3 | c.677del p.P226Rfs*52 | Frame Shift Del (DEL) | VAF 7/29 reads (24%) | catalogued as COSV54711577; called by mutect2, pindel, varscan2
- KLF8 | c.7G>A p.D3N | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.1); catalogued as COSV63847768; called by muse, mutect2, varscan2
- KLHL10 | c.755G>A p.S252N | Missense Mutation (SNP) | VAF 13/112 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV53172614; called by muse, mutect2, varscan2
- KLHL22 | c.767G>A p.R256Q | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.006); catalogued as rs138560799; called by muse, mutect2, varscan2
- KMT2A | c.10817A>G p.Q3606R | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as COSV63285626; called by muse, mutect2, varscan2
- KMT2C | c.5349_5351dup p.Q1787dup | In Frame Ins (INS) | VAF 26/186 reads (14%) | catalogued as rs749417254; called by mutect2, varscan2
- KMT2C | c.3862C>T p.R1288W | Missense Mutation (SNP) | VAF 24/159 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1301632462, COSV51395722; called by muse, mutect2, varscan2
- KMT2C | c.568C>T p.R190* | Nonsense Mutation (SNP) | VAF 62/461 reads (13%) | catalogued as COSV51436648; called by muse, mutect2, varscan2
- KNCN | c.88G>A p.G30S | Missense Mutation (SNP) | VAF 31/178 reads (17%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.846); catalogued as rs201613509, COSV53814656; called by muse, mutect2, varscan2
- KRI1 | c.1133G>A p.G378D | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0.22); catalogued as COSV57264470; called by muse, mutect2, varscan2
- KRT9 | c.1667G>A p.G556D | Missense Mutation (SNP) | VAF 35/246 reads (14%) | SIFT tolerated, low confidence (0.14); PolyPhen possibly damaging (0.822); catalogued as COSV55852982; called by muse, mutect2, varscan2
- KRTAP19-7 | c.28G>T p.G10C | Missense Mutation (SNP) | VAF 17/130 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.824); catalogued as COSV58366148; called by muse, mutect2, varscan2
- KSR2 | c.1769A>G p.Q590R | Missense Mutation (SNP) | VAF 16/132 reads (12%) | SIFT tolerated (0.22); PolyPhen benign (0.316); catalogued as COSV100196546; called by muse, mutect2, varscan2
- LAMA2 | c.745C>T p.R249C | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs376437110; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LAMA2 | c.7889G>A p.R2630Q | Missense Mutation (SNP) | VAF 14/97 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs774656522, COSV70346451; called by muse, mutect2, varscan2
- LBX2 | c.409C>T p.R137* (on ENST00000377566 / NM_001282430.2; = p.R133* on NM_001009812.2) | Nonsense Mutation (SNP) | VAF 15/78 reads (19%) | catalogued as COSV99282342; called by muse, mutect2, varscan2
- LDHAL6B | c.73G>A p.G25R | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0); catalogued as rs778599098, COSV55686727, COSV55688342; called by muse, mutect2, varscan2
- LENG8 | c.1534C>T p.R512W | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs752252647, COSV58727615; called by muse, varscan2
- LENG8 | c.1565G>A p.R522H | Missense Mutation (SNP) | VAF 32/66 reads (48%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.469); catalogued as rs775233160, COSV58727623; called by muse, varscan2
- LHCGR | c.1764dup p.A589Cfs*17 | Frame Shift Ins (INS) | VAF 18/106 reads (17%) | catalogued as rs1293879367; called by mutect2, varscan2
- LIMD2 | c.61A>G p.S21G | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs367901623; called by mutect2, varscan2
- LIMK2 | c.980G>A p.R327Q | Missense Mutation (SNP) | VAF 8/84 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as rs1238079205, COSV59182313; called by muse, mutect2, varscan2
- LINC02210-CRHR1 | c.641C>T p.A214V | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT tolerated (0.69); PolyPhen benign (0.013); catalogued as COSV53275994, COSV53278487; called by muse, mutect2, varscan2
- LIPJ | c.833del p.G278Afs*5 | Frame Shift Del (DEL) | VAF 9/66 reads (14%) | catalogued as rs774467715, COSV100905926; called by mutect2, pindel, varscan2
- LIX1 | c.182C>A p.A61D | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as COSV57206863; called by muse, mutect2, varscan2
- LMO4 | c.308C>T p.A103V | Missense Mutation (SNP) | VAF 5/60 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.113); catalogued as COSV65170246; called by muse, mutect2
- LPAR3 | c.40dup p.Y14Lfs*2 | Frame Shift Ins (INS) | VAF 20/158 reads (13%) | catalogued as rs767032705; called by mutect2, varscan2
- LRGUK | c.1633C>T p.R545W | Missense Mutation (SNP) | VAF 15/121 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs769875662, COSV53636041; called by muse, mutect2, varscan2
- LRP1 | c.883T>C p.Y295H | Missense Mutation (SNP) | VAF 10/114 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV54510478; called by muse, mutect2
- LRP1 | c.10273C>T p.R3425C | Missense Mutation (SNP) | VAF 44/161 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54510487; called by muse, mutect2, varscan2
- LRP12 | c.1640C>T p.P547L | Missense Mutation (SNP) | VAF 12/104 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52628546; called by muse, varscan2
- LRP1B | c.4495A>G p.T1499A | Missense Mutation (SNP) | VAF 35/209 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.125); catalogued as COSV101260170; called by muse, mutect2, varscan2
- LRP4 | c.800C>T p.T267I | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT tolerated (0.14); PolyPhen benign (0.084); catalogued as COSV66135686; called by muse, mutect2, varscan2
- LRRC36 | c.1465C>A p.H489N | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.035); catalogued as COSV52079558; called by muse, mutect2, varscan2
- LRRC49 | c.811C>A p.L271I | Missense Mutation (SNP) | VAF 17/100 reads (17%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.831); catalogued as COSV53010485; called by muse, mutect2, varscan2
- LRRC49 | c.1430A>C p.N477T | Missense Mutation (SNP) | VAF 17/102 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV53010493; called by muse, mutect2, varscan2
- LRRFIP2 | c.163C>T p.R55* | Nonsense Mutation (SNP) | VAF 14/109 reads (13%) | catalogued as rs1439185967, COSV60867526; called by muse, mutect2, varscan2
- LRRN3 | c.1820T>C p.V607A | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.081); catalogued as COSV100073052; called by muse, mutect2
- LRRTM4 | c.605C>A p.A202D | Missense Mutation (SNP) | VAF 6/84 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.928); catalogued as COSV101297716; called by muse, mutect2
- LSR | c.1070C>A p.P357H (on ENST00000361790; = p.P338H on NM_015925.6) | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.275); catalogued as COSV55886998; called by muse, mutect2, varscan2
- LTBP4 | c.4224del p.A1409Hfs*20 (on ENST00000308370 / NM_001042544.1; = p.A1372Hfs*20 on NM_003573.2) | Frame Shift Del (DEL) | VAF 8/26 reads (31%) | catalogued as rs754757253, COSV52588935; called by mutect2, varscan2
- LVRN | c.352G>A p.D118N | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT tolerated (0.19); PolyPhen benign (0.012); catalogued as COSV100773661; called by muse, mutect2
- LY6G6F-LY6G6D | c.350A>G p.N117S | Missense Mutation (SNP) | VAF 17/105 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV65442812; called by muse, mutect2, varscan2
- LYPD2 | c.203C>T p.T68M | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as rs781424827, COSV63649364; called by muse, mutect2, varscan2
- LYST | c.1056T>A p.N352K | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.73); catalogued as COSV67706727; called by muse, mutect2, varscan2
- LYZL1 | c.567del p.G190Afs*19 (on ENST00000375500; = p.G144Afs*19 on NM_032517.6) | Frame Shift Del (DEL) | VAF 7/68 reads (10%) | catalogued as rs1376851399, COSV64966279; called by mutect2, pindel, varscan2
- LZTS3 | c.1967A>T p.E656V (on ENST00000329152; = p.E610V on NM_001282533.2) | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.448); catalogued as COSV53905954; called by muse, mutect2, varscan2
- MACF1 | c.21100C>T p.R7034C (on ENST00000372915; = p.R5079C on NM_012090.5) | Missense Mutation (SNP) | VAF 24/150 reads (16%) | catalogued as rs747182535, COSV57108915; called by muse, mutect2, varscan2
- MAF | c.1097C>T p.P366L | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100391989, COSV58153837; called by muse, mutect2, varscan2
- MAGEA12 | c.776G>A p.R259Q | Missense Mutation (SNP) | VAF 48/134 reads (36%) | SIFT tolerated (0.35); PolyPhen benign (0.208); catalogued as COSV63294762; called by muse, mutect2, varscan2
- MAGED2 | c.990+2T>C p.X330_splice | Splice Site (SNP) | VAF 26/76 reads (34%) | catalogued as COSV54497800; called by muse, mutect2, varscan2
- MAGI2 | c.2269C>T p.Q757* | Nonsense Mutation (SNP) | VAF 10/72 reads (14%) | catalogued as rs747282945, COSV62646014, COSV62656132; called by mutect2, varscan2
- MAGI2 | c.104del p.G35Afs*13 | Frame Shift Del (DEL) | VAF 10/56 reads (18%) | catalogued as COSV62634980; called by mutect2, pindel, varscan2
- MANEA | c.619A>G p.T207A | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT tolerated (0.85); PolyPhen benign (0.001); catalogued as COSV100721655; called by muse, mutect2, varscan2
- MAP3K15 | c.2881G>A p.A961T | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs765404542, COSV58829723; called by muse, mutect2, varscan2
- MAP3K4 | c.479del p.N160Mfs*8 | Frame Shift Del (DEL) | VAF 15/84 reads (18%) | catalogued as COSV62334603; called by mutect2, varscan2
- MAP7 | c.1945C>T p.P649S | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT tolerated (0.31); PolyPhen benign (0.284); catalogued as COSV63419380; called by muse, mutect2, varscan2
- MAPK8 | c.123C>T p.C41= | Splice Region (SNP) | VAF 10/64 reads (16%) | catalogued as rs778730942, COSV64410494; called by muse, mutect2
- MARCHF8 | c.5G>A p.S2N | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0); catalogued as COSV60572150; called by muse, mutect2, varscan2
- MARK2 | c.1081C>A p.L361M | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV59283155; called by muse, mutect2, varscan2
- MBD6 | c.716C>T p.P239L | Missense Mutation (SNP) | VAF 10/77 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.217); catalogued as COSV63074364; called by muse, mutect2
- MBD6 | c.2200dup p.Q734Pfs*4 | Frame Shift Ins (INS) | VAF 12/70 reads (17%) | catalogued as rs749738168; called by mutect2, varscan2
- MBNL2 | c.724G>A p.A242T | Missense Mutation (SNP) | VAF 3/21 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.627); catalogued as rs1275656847, COSV59121186; called by muse, mutect2
- MCCC2 | c.242T>G p.L81R | Missense Mutation (SNP) | VAF 7/67 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.978); catalogued as COSV100040522; called by mutect2, varscan2
- MCM3AP | c.1777A>G p.S593G | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT tolerated (0.26); PolyPhen benign (0.01); catalogued as COSV99387459; called by muse, mutect2, varscan2
- MCOLN1 | c.594del p.E199Sfs*39 | Frame Shift Del (DEL) | VAF 40/268 reads (15%) | catalogued as rs1349755445, COSV51177134; called by pindel, varscan2
- MEAK7 | c.800G>A p.C267Y | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs572528553, COSV100640449; called by mutect2, varscan2
- MECOM | c.1839del p.G614Efs*30 (on ENST00000468789 / NM_001105078.4; = p.G802Efs*30 on NM_004991.4) | Frame Shift Del (DEL) | VAF 19/120 reads (16%) | catalogued as rs773080349; called by mutect2, pindel, varscan2
- MED12 | c.4068G>A p.M1356I | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.024); catalogued as COSV61339270; called by muse, mutect2, varscan2
- MED13 | c.1412G>A p.R471H | Missense Mutation (SNP) | VAF 72/476 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs745571684, COSV67263392; called by muse, mutect2, varscan2
- MEF2C | c.1151C>G p.S384C | Missense Mutation (SNP) | VAF 40/228 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as COSV60930463; called by muse, mutect2, varscan2
- MEGF10 | c.3184G>A p.A1062T | Missense Mutation (SNP) | VAF 10/77 reads (13%) | SIFT tolerated (0.55); PolyPhen benign (0.001); catalogued as COSV57248763; called by muse, mutect2, varscan2
- MEIS2 | c.938C>T p.A313V (on ENST00000561208 / NM_170675.5; = p.A300V on NM_002399.3) | Missense Mutation (SNP) | VAF 46/312 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs1275580589, COSV54933650, COSV99576255; called by muse, varscan2
- MELTF | c.732G>T p.W244C | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56381052; called by muse, mutect2, varscan2
- MEOX2 | c.470C>T p.A157V | Missense Mutation (SNP) | VAF 22/123 reads (18%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs1421793823, COSV100012491, COSV56287804; called by muse, mutect2, varscan2
- METTL8 | c.360A>C p.K120N | Missense Mutation (SNP) | VAF 18/102 reads (18%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as COSV100931105; called by muse, mutect2, varscan2
- MEX3B | c.448G>A p.A150T | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as COSV61663399; called by muse, mutect2, varscan2
- MFAP5 | c.236del p.N79Ifs*57 | Frame Shift Del (DEL) | VAF 8/52 reads (15%) | catalogued as rs746355340; called by mutect2, varscan2
- MFSD11 | c.272C>T p.A91V | Missense Mutation (SNP) | VAF 40/256 reads (16%) | SIFT tolerated (0.14); PolyPhen benign (0.057); catalogued as COSV60623545; called by muse, mutect2, varscan2
- MGA | c.3744del p.E1249Rfs*42 | Frame Shift Del (DEL) | VAF 19/122 reads (16%) | catalogued as rs1193719928; called by mutect2, varscan2
- MGAT3 | c.193G>T p.G65* | Nonsense Mutation (SNP) | VAF 9/53 reads (17%) | catalogued as COSV100361878, COSV57865289; called by muse, mutect2, varscan2
- MIA2 | c.1089del p.D364Tfs*8 | Frame Shift Del (DEL) | VAF 14/82 reads (17%) | catalogued as rs538500709; called by mutect2, varscan2
- MIB1 | c.574G>A p.A192T | Missense Mutation (SNP) | VAF 21/74 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as rs771020731, COSV55090281; called by muse, mutect2, varscan2
- MIDN | c.992G>A p.R331H | Missense Mutation (SNP) | VAF 13/79 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.65); catalogued as rs753884875, COSV56294966; called by muse, mutect2, varscan2
- MIDN | c.1339G>A p.D447N | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as rs764769740, COSV56294973; called by muse, mutect2, varscan2
- MINK1 | c.2579C>T p.T860I | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.969); catalogued as rs1271039757, COSV53417902; called by muse, mutect2, varscan2
- MISP | c.664G>T p.G222C | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT tolerated (0.21); PolyPhen benign (0.02); catalogued as COSV53119994; called by muse, mutect2, varscan2
- MKS1 | c.842G>A p.R281Q | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV58303927; called by muse, mutect2, varscan2
- MLXIPL | c.518G>A p.R173H | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1403010158, COSV57668094; called by muse, mutect2
- MME | c.268G>T p.G90C | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64707259; called by muse, mutect2
- MMP11 | c.1223A>G p.Y408C | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs778551635, COSV53156179; called by muse, mutect2, varscan2
- MNDA | c.1118A>G p.Q373R | Missense Mutation (SNP) | VAF 20/116 reads (17%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.871); catalogued as COSV63740740, COSV63741747; called by muse, mutect2, varscan2
- MNT | c.1574C>A p.S525* | Nonsense Mutation (SNP) | VAF 15/91 reads (16%) | catalogued as COSV51511997; called by muse, mutect2, varscan2
- MPP1 | c.1183C>T p.P395S | Missense Mutation (SNP) | VAF 23/79 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV101054010; called by muse, mutect2, varscan2
- MPZ | c.136del p.V46* | Frame Shift Del (DEL) | VAF 8/56 reads (14%) | catalogued as CD1411850, CD1511286; called by mutect2, varscan2
- MRC2 | c.2854C>T p.R952C | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1336282999, COSV57639534; called by muse, mutect2, varscan2
- MROH1 | c.4112G>A p.R1371H | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs898597007; called by muse, mutect2, varscan2
- MROH9 | c.256G>T p.G86W | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV63011205; called by muse, mutect2, varscan2
- MRPL2 | c.896C>A p.P299H | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99539164; called by muse, mutect2, varscan2
- MRPL54 | c.52del p.A18Pfs*5 | Frame Shift Del (DEL) | VAF 5/45 reads (11%) | catalogued as COSV57462495; called by mutect2, pindel, varscan2
- MRPS10 | c.136C>T p.Q46* | Nonsense Mutation (SNP) | VAF 19/116 reads (16%) | catalogued as COSV50002371, COSV99273503; called by muse, mutect2, varscan2
- MRPS6 | c.90G>T p.M30I | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.033); catalogued as COSV62969543; called by muse, varscan2
- MS4A2 | c.592T>C p.S198P | Missense Mutation (SNP) | VAF 37/144 reads (26%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.94); catalogued as COSV54012437; called by muse, mutect2, varscan2
- MSANTD4 | c.821C>T p.P274L | Missense Mutation (SNP) | VAF 44/297 reads (15%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.982); catalogued as rs1301125098, COSV100108632, COSV57285753; called by muse, mutect2, varscan2
- MST1R | c.3235C>T p.R1079W | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as rs780949671, COSV56568540; called by muse, mutect2, varscan2
- MT1M | c.88A>G p.K30E | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.225); catalogued as COSV65835724; called by muse, mutect2, varscan2
- MTMR12 | c.734T>C p.V245A | Missense Mutation (SNP) | VAF 27/172 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.787); catalogued as rs1227367384, COSV53784140; called by muse, mutect2, varscan2
- MTUS2 | c.3044C>T p.A1015V | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as rs201118258, COSV70919028; called by mutect2, varscan2
- MTX3 | c.380C>A p.A127D | Missense Mutation (SNP) | VAF 21/119 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV72512290; called by muse, mutect2, varscan2
- MUC16 | c.10094C>A p.S3365Y | Missense Mutation (SNP) | VAF 27/151 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.957); catalogued as COSV67463815; called by muse, mutect2, varscan2
- MUC16 | c.7390G>A p.A2464T | Missense Mutation (SNP) | VAF 28/242 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.059); catalogued as COSV67463822; called by muse, mutect2
- MUC16 | c.5774C>T p.S1925F | Missense Mutation (SNP) | VAF 22/140 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.919); catalogued as COSV67463828; called by muse, mutect2, varscan2
- MUC17 | c.13318C>T p.P4440S | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.19); catalogued as COSV60287808; called by muse, mutect2, varscan2
- MXRA8 | c.965G>A p.R322H | Missense Mutation (SNP) | VAF 36/110 reads (33%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.765); catalogued as rs61730211, COSV58509960; called by muse, mutect2, varscan2
- MYADM | c.136T>G p.S46A | Missense Mutation (SNP) | VAF 38/99 reads (38%) | SIFT tolerated (1); PolyPhen probably damaging (0.989); catalogued as COSV61239268; called by muse, mutect2, varscan2
- MYADM | c.410C>T p.A137V | Missense Mutation (SNP) | VAF 8/81 reads (10%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.657); catalogued as COSV61239275; called by muse, mutect2, varscan2
- MYCBP2 | c.5288G>A p.G1763E (on ENST00000357337; = p.G1801E on NM_015057.5) | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.712); catalogued as COSV62018116; called by muse, mutect2
- MYCBPAP | c.1146C>T p.Y382= | Splice Region (SNP) | VAF 15/96 reads (16%) | catalogued as rs750379366, COSV60407595; called by muse, mutect2, varscan2
- MYD88 | c.518A>C p.Q173P | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT tolerated (0.29); PolyPhen benign (0.006); catalogued as COSV100086407; called by muse, mutect2, varscan2
- MYH13 | c.4556A>G p.Q1519R | Missense Mutation (SNP) | VAF 18/117 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.794); catalogued as COSV52827781; called by mutect2, varscan2
- MYH13 | c.3227A>G p.D1076G | Missense Mutation (SNP) | VAF 17/94 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.692); catalogued as COSV52827808; called by muse, mutect2, varscan2
- MYLIP | c.1184T>A p.I395N | Missense Mutation (SNP) | VAF 13/87 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); catalogued as COSV62766713; called by muse, mutect2, varscan2
- MYO18B | c.5618G>A p.R1873Q | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.034); catalogued as rs765439956, COSV59133694; called by mutect2, varscan2
- MYO1C | c.496C>T p.R166C (on ENST00000648651 / NM_001080779.2; = p.R131C on NM_033375.5) | Missense Mutation (SNP) | VAF 15/74 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.806); catalogued as rs769587880, COSV62999081; called by muse, mutect2, varscan2
- MYO7B | c.3004G>A p.E1002K | Missense Mutation (SNP) | VAF 26/153 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.439); catalogued as rs574346274, COSV67347421; called by muse, mutect2, varscan2
- MYO7B | c.4558C>T p.L1520F | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as COSV67347426, COSV67348327; called by muse, mutect2
- MYOCD | c.934C>T p.R312* | Nonsense Mutation (SNP) | VAF 14/80 reads (18%) | catalogued as COSV58503193; called by muse, varscan2
- MYOM1 | c.109G>A p.A37T | Missense Mutation (SNP) | VAF 25/84 reads (30%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.692); catalogued as rs1443057939, COSV55291340, COSV55301719; called by muse, mutect2, varscan2
- N4BP3 | c.4G>A p.A2T | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.214); catalogued as COSV51062602; called by muse, mutect2, varscan2
- NAA80 | c.716C>A p.P239H (on ENST00000417393 / NM_001200018.2; = p.P261H on NM_012191.4) | Missense Mutation (SNP) | VAF 18/138 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.831); catalogued as COSV56497482; called by muse, mutect2, varscan2
- NAALADL1 | c.2027G>A p.R676H | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.781); catalogued as rs369091785; called by muse, mutect2, varscan2
- NABP2 | c.194G>A p.G65E | Missense Mutation (SNP) | VAF 36/137 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57212412; called by muse, mutect2, varscan2
- NACA | c.626C>T p.A209V | Missense Mutation (SNP) | VAF 15/125 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.055); catalogued as COSV63267767; called by muse, mutect2, varscan2
- NACC1 | c.71G>A p.R24Q | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV52834248; called by muse, mutect2, varscan2
- NAGPA | c.1525G>A p.A509T | Missense Mutation (SNP) | VAF 8/32 reads (25%) | PolyPhen benign (0); catalogued as rs765209071, COSV56569872; called by mutect2, varscan2
- NAIF1 | c.679G>A p.A227T | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.978); catalogued as rs147281899, COSV66090835, COSV66091326; called by muse, mutect2, varscan2
- NAP1L2 | c.52G>A p.A18T | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as COSV65172477; called by muse, mutect2, varscan2
- NAPEPLD | c.539C>T p.A180V | Missense Mutation (SNP) | VAF 17/143 reads (12%) | SIFT tolerated (0.16); PolyPhen benign (0.131); catalogued as rs367936558; called by muse, mutect2, varscan2
- NAV1 | c.4742G>A p.R1581H | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.975); catalogued as rs369328574; called by muse, mutect2, varscan2
- NAV3 | c.6244del p.T2082Qfs*22 (on ENST00000397909 / NM_001024383.2; = p.T2060Qfs*22 on NM_014903.6) | Frame Shift Del (DEL) | VAF 9/80 reads (11%) | catalogued as COSV57072414; called by mutect2, pindel, varscan2
- NAXD | c.748G>A p.D250N | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs775128133, COSV59395389; called by muse, mutect2, varscan2
- NBAS | c.3898G>A p.A1300T | Missense Mutation (SNP) | VAF 13/85 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.943); catalogued as rs776508998, COSV55720785; called by muse, mutect2, varscan2
- NBEAL1 | c.4838A>G p.Y1613C | Missense Mutation (SNP) | VAF 22/138 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.733); catalogued as COSV101495773; called by muse, mutect2, varscan2
- NBEAL2 | c.3109G>A p.V1037M | Missense Mutation (SNP) | VAF 21/80 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.939); catalogued as rs557357830, COSV52754594, COSV52757559; called by muse, mutect2, varscan2
- NCDN | c.1838C>T p.P613L | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.197); catalogued as rs148888595; called by mutect2, varscan2
- NCF4 | c.1010C>T p.T337M | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs147550660; called by muse, mutect2, varscan2
- NCOA7 | c.2320C>T p.P774S | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV57655138; called by muse, mutect2, varscan2
- NCOR1 | c.3098C>T p.P1033L | Missense Mutation (SNP) | VAF 16/104 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs776976570, COSV51973727; called by muse, mutect2, varscan2
- NDUFB5 | c.469C>T p.R157* | Nonsense Mutation (SNP) | VAF 20/146 reads (14%) | catalogued as rs143453890, COSV52020034; called by muse, mutect2, varscan2
- NDUFS1 | c.767C>T p.A256V | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs773373927, COSV51909521; called by mutect2, varscan2
- NEFM | c.638C>T p.A213V | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.195); catalogued as COSV55330703; called by muse, mutect2, varscan2
- NEFM | c.1027C>T p.R343W | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55332003; called by muse, mutect2, varscan2
- NEK9 | c.2364G>T p.M788I | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0); catalogued as COSV53130922; called by mutect2, varscan2
- NFASC | c.2816C>T p.A939V | Missense Mutation (SNP) | VAF 30/204 reads (15%) | SIFT tolerated (0.51); PolyPhen benign (0.003); catalogued as rs573424743, COSV58360105; called by muse, varscan2
- NFATC4 | c.1801G>T p.G601C | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51602002; called by muse, mutect2, varscan2
- NHSL2 | c.1912G>A p.V638I (on ENST00000510661; = p.V1004I on NM_001013627.2) | Missense Mutation (SNP) | VAF 52/121 reads (43%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.503); catalogued as rs937347346, COSV65453336; called by muse, mutect2, varscan2
- NID2 | c.3323C>T p.T1108I | Missense Mutation (SNP) | VAF 16/101 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.339); catalogued as rs753534469, COSV53496126; called by muse, mutect2, varscan2
- NIPBL | c.8326del p.I2776Lfs*3 | Frame Shift Del (DEL) | VAF 6/43 reads (14%) | catalogued as rs1157335847; called by mutect2, pindel, varscan2
- NLRC4 | c.517A>G p.K173E | Missense Mutation (SNP) | VAF 20/103 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV61592551; called by muse, mutect2, varscan2
- NOBOX | c.487del p.R163Afs*11 | Frame Shift Del (DEL) | VAF 4/40 reads (10%) | catalogued as rs754069719; called by mutect2, pindel
- NOTCH1 | c.5819G>A p.R1940H | Missense Mutation (SNP) | VAF 33/112 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); catalogued as rs897872809, COSV53049642; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NR2F1 | c.463G>A p.A155T | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.031); catalogued as COSV59068265; called by muse, mutect2, varscan2
- NRG3 | c.1028C>T p.T343I | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT tolerated (0.41); PolyPhen probably damaging (0.991); catalogued as COSV64559986; called by muse, mutect2, varscan2
- NRIP1 | c.2184del p.E729Rfs*5 | Frame Shift Del (DEL) | VAF 16/99 reads (16%) | catalogued as rs776154715; called by mutect2, varscan2
- NRSN2 | c.161G>A p.R54H | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT tolerated (0.81); PolyPhen benign (0); catalogued as rs139750306; called by muse, mutect2, varscan2
- NT5C2 | c.1618G>C p.A540P | Missense Mutation (SNP) | VAF 40/241 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV58416087; called by muse, mutect2, varscan2
- NTNG2 | c.676G>A p.D226N | Missense Mutation (SNP) | VAF 12/88 reads (14%) | SIFT tolerated (0.25); PolyPhen benign (0.13); catalogued as rs766504033, COSV62366484, COSV62367249; called by muse, varscan2
- NTRK1 | c.2318G>A p.S773N | Missense Mutation (SNP) | VAF 11/101 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV62325431; called by muse, mutect2, varscan2
- NUAK1 | c.116C>T p.P39L | Missense Mutation (SNP) | VAF 21/91 reads (23%) | SIFT tolerated (0.05); PolyPhen benign (0.017); catalogued as rs1169618816, COSV54603069; called by muse, mutect2, varscan2
- NUDT14 | c.199G>A p.A67T | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.657); catalogued as rs1403727516, COSV59650369; called by muse, mutect2
- NUDT22 | c.152C>T p.A51V | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.076); catalogued as rs1230966766, COSV99656024; called by muse, mutect2
- NUMBL | c.1666C>T p.R556C | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.586); catalogued as rs1245095084, COSV53285306; called by muse, mutect2
- NUP133 | c.2387A>G p.N796S | Missense Mutation (SNP) | VAF 22/123 reads (18%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as rs1405176384, COSV54570861; called by muse, mutect2, varscan2
- NUP210L | c.2740G>A p.D914N | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT tolerated (0.16); PolyPhen benign (0.017); catalogued as COSV99668910; called by mutect2, varscan2
- NUP210L | c.2072del p.L691Wfs*3 | Frame Shift Del (DEL) | VAF 14/76 reads (18%) | catalogued as rs760869296; called by mutect2, varscan2
- NUP214 | c.681del p.V228Sfs*29 | Frame Shift Del (DEL) | VAF 27/120 reads (23%) | catalogued as rs771913112, COSV63912486; called by mutect2, varscan2
- NUP98 | c.3035G>A p.R1012H (on ENST00000359171 / NM_001365126.1; = p.R995H on NM_016320.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/91 reads (15%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs138515480; called by muse, mutect2, varscan2
- NXT1 | c.128C>T p.A43V | Missense Mutation (SNP) | VAF 23/134 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.68); catalogued as COSV54782925; called by muse, mutect2, varscan2
- OAS2 | c.1228G>A p.D410N | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.018); catalogued as rs1277427368, COSV60801976; called by muse, mutect2, varscan2
- OBI1 | c.863A>T p.D288V | Missense Mutation (SNP) | VAF 16/131 reads (12%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV56145529; called by muse, mutect2, varscan2
- OBSCN | c.4237T>G p.C1413G | Missense Mutation (SNP) | VAF 19/199 reads (10%) | SIFT tolerated (0.89); PolyPhen benign (0); catalogued as COSV52747034, COSV52771736; called by muse, mutect2
- OCA2 | c.292A>G p.T98A | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.452); catalogued as rs1183314534, COSV100668564; called by mutect2, varscan2
- OCIAD2 | c.268G>A p.A90T | Missense Mutation (SNP) | VAF 23/142 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV56716621; called by muse, mutect2, varscan2
- ODF2 | c.1251G>T p.E417D (on ENST00000434106 / NM_153433.2; = p.E393D on NM_002540.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/87 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as COSV63546904; called by muse, mutect2, varscan2
- OLFML2B | c.1006C>A p.L336M | Missense Mutation (SNP) | VAF 14/95 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.865); catalogued as COSV54196151; called by muse, mutect2, varscan2
- OPN3 | c.416G>A p.R139H | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as rs777101745, COSV100086987, COSV59364065; called by muse, mutect2, varscan2
- OPN5 | c.319C>T p.R107C | Missense Mutation (SNP) | VAF 21/115 reads (18%) | SIFT tolerated (0.19); PolyPhen benign (0.025); catalogued as rs1219866609, COSV55245406; called by muse, mutect2, varscan2
- OR10G4 | c.223A>T p.T75S | Missense Mutation (SNP) | VAF 33/250 reads (13%) | SIFT tolerated (0.4); PolyPhen benign (0.164); catalogued as COSV100304960; called by muse, mutect2, varscan2
- OR1L3 | c.355G>A p.A119T | Missense Mutation (SNP) | VAF 30/108 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59169772; called by muse, mutect2, varscan2
- OR1Q1 | c.322G>A p.A108T | Missense Mutation (SNP) | VAF 33/244 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.011); catalogued as rs775441414, COSV52917886; called by muse, mutect2, varscan2
- OR2D2 | c.532T>C p.F178L | Missense Mutation (SNP) | VAF 26/120 reads (22%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.544); catalogued as COSV100203914; called by muse, mutect2, varscan2
- OR2T12 | c.340G>A p.A114T | Missense Mutation (SNP) | VAF 28/206 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.117); catalogued as COSV58777422; called by muse, mutect2, varscan2
- OR4A16 | c.52G>T p.D18Y | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.092); catalogued as rs541874934, COSV59042483; called by muse, mutect2, varscan2
- OR4C6 | c.19G>A p.V7M | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.089); catalogued as COSV58604346, COSV58606857; called by muse, mutect2
- OR52D1 | c.557G>A p.G186D | Missense Mutation (SNP) | VAF 6/69 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100495320; called by muse, mutect2, varscan2
- OR5D14 | c.932T>C p.V311A | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV100162573, COSV59457296; called by muse, mutect2
- OR6B2 | c.569C>T p.T190M | Missense Mutation (SNP) | VAF 38/237 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.258); catalogued as rs376608868, COSV53154852; called by muse, mutect2, varscan2
- OR6C2 | c.475A>C p.S159R | Missense Mutation (SNP) | VAF 12/104 reads (12%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.062); catalogued as COSV59516015; called by mutect2, varscan2
1,121 further variants in this file (704 protein-altering or splice-affecting, 381 silent, 36 other) are not listed here.
